Somatic mutation profile of cancer-model specimen HCM-BROD-0025-C16-85A (3D Organoid, passage 9; aliquot HCM-BROD-0025-C16-85A-01D-A80U-36), derived from the primary tumor of HCMI case HCM-BROD-0025-C16, project HCMI-CMDC (NCI Cancer Model Development for the Human Cancer Model Initiative). Sex at birth: male; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Stomach, NOS; AJCC pathologic stage: Stage IIIA; Tumor grade: G3; Age at diagnosis: 73.7 years (26,928 days).
Specimen HCM-BROD-0025-C16-85A: Sample type: Next Generation Cancer Model; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: 3D Organoid; Preservation method: Frozen; Passage count: 9.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 4deb202b-db85-48ca-ae91-a95669055d54.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen HCM-BROD-0025-C16-10A (Blood Derived Normal), aliquot HCM-BROD-0025-C16-10A-01D-A80U-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/cac52f5d-2afa-4f20-9bee-d690d783a0e7

The open-access MAF lists 1,422 somatic variants for this specimen: 1,008 protein-altering or splice-affecting, 352 silent, 62 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 733, Silent 352, Frame Shift Del 169, Nonsense Mutation 38, Frame Shift Ins 37, Intron 30, In Frame Del 14, 3'UTR 11, Splice Region 8, 5'UTR 8, Splice Site 7, 5'Flank 6.

Variants (750 of 1,422; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ARID1A | c.4381C>T p.R1461* | Nonsense Mutation (SNP) | VAF 230/526 reads (44%) | hotspot (GDC flag); catalogued as COSV61376088; called by muse, varscan2
- C19orf12 | c.395T>A p.L132Q (on ENST00000392278 / NM_001031726.3; = p.L121Q on NM_031448.6) | Missense Mutation (SNP) | VAF 328/612 reads (54%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as rs387907173, CM131542; ClinVar: pathogenic; called by muse, mutect2, varscan2
- CAPN3 | c.1343G>A p.R448H | Missense Mutation (SNP) | VAF 134/290 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs863224956, CM129344, CM990311, COSV58826312; ClinVar: pathogenic; called by muse, mutect2, varscan2
- KCNQ1 | c.1201del p.R401Gfs*18 | Frame Shift Del (DEL) | VAF 69/532 reads (13%) | catalogued as rs397508082, CX097215, COSV50099837; ClinVar: pathogenic; called by mutect2, pindel, varscan2
- KMT2B | c.521del p.P174Qfs*20 | Frame Shift Del (DEL) | VAF 411/982 reads (42%) | catalogued as rs763183959; ClinVar: pathogenic; called by mutect2, pindel, varscan2
- KRAS | c.35G>A p.G12D | Missense Mutation (SNP) | VAF 125/289 reads (43%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen benign (0.303); catalogued as rs121913529, COSV55497369, COSV55497419, COSV55497479; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- LARP7 | c.1213del p.T405Qfs*5 | Frame Shift Del (DEL) | VAF 106/207 reads (51%) | catalogued as rs750946801; ClinVar: likely pathogenic; called by mutect2, varscan2
- NKX2-1 | c.254del p.G85Afs*10 | Frame Shift Del (DEL) | VAF 94/601 reads (16%) | catalogued as rs587776709; ClinVar: pathogenic; called by mutect2, varscan2
- TP53 | c.733G>A p.G245S | Missense Mutation (SNP) | VAF 191/393 reads (49%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs28934575, CM010463, CM900210, CM920674, COSV52661744, COSV52661877, COSV52713951, COSV52839866; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- WRN | c.3382del p.S1128Vfs*34 | Frame Shift Del (DEL) | VAF 46/123 reads (37%) | catalogued as rs778872619; ClinVar: pathogenic; called by mutect2, pindel, varscan2
- ABCA3 | c.1024G>A p.D342N | Missense Mutation (SNP) | VAF 174/336 reads (52%) | SIFT tolerated (0.06); PolyPhen benign (0.336); catalogued as rs148726153; called by muse, mutect2, varscan2
- ABCB4 | c.1447T>C p.S483P | Missense Mutation (SNP) | VAF 208/399 reads (52%) | SIFT deleterious (0); PolyPhen benign (0.431); catalogued as COSV55935898; called by muse, mutect2, varscan2
- ABCD1 | c.514C>T p.R172C | Missense Mutation (SNP) | VAF 433/869 reads (50%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.697); catalogued as rs782653223, CD105357; called by muse, mutect2, varscan2
- ABHD16B | c.236C>T p.A79V | Missense Mutation (SNP) | VAF 408/1127 reads (36%) | SIFT tolerated (0.29); PolyPhen benign (0.023); catalogued as rs765475843; called by muse, mutect2, varscan2
- ADAM18 | c.478A>G p.I160V | Missense Mutation (SNP) | VAF 176/343 reads (51%) | SIFT tolerated (0.3); PolyPhen benign (0.005); catalogued as rs1250959336; called by muse, varscan2
- ADAMTS12 | c.200dup p.L67Ffs*39 | Frame Shift Ins (INS) | VAF 158/405 reads (39%) | catalogued as rs1181397524; called by mutect2, pindel, varscan2
- ADAMTS2 | c.3139C>T p.R1047C | Missense Mutation (SNP) | VAF 187/416 reads (45%) | SIFT deleterious (0); PolyPhen possibly damaging (0.549); catalogued as rs758048360, COSV52388571; called by muse, mutect2, varscan2
- ADAMTS7 | c.2387A>G p.Q796R | Missense Mutation (SNP) | VAF 26/418 reads (6%) | SIFT deleterious (0.03); PolyPhen benign (0.2); catalogued as rs1377586626; called by muse, mutect2
- ADCY3 | c.1890G>T p.K630N | Missense Mutation (SNP) | VAF 230/495 reads (46%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.482); catalogued as rs371180476; called by muse, mutect2, varscan2
- ADCY9 | c.3659G>A p.G1220D | Missense Mutation (SNP) | VAF 44/558 reads (8%) | SIFT tolerated (0.24); PolyPhen benign (0.143); catalogued as rs201893525; called by muse, mutect2
- ADPRHL1 | c.1230dup p.S411Efs*206 | Frame Shift Ins (INS) | VAF 422/1026 reads (41%) | catalogued as rs1299889061; called by mutect2, pindel, varscan2
- AFF1 | c.3201del p.D1068Tfs*2 | Frame Shift Del (DEL) | VAF 144/300 reads (48%) | catalogued as rs1212211089; called by mutect2, varscan2
- AGPS | c.1543C>T p.R515* | Nonsense Mutation (SNP) | VAF 102/225 reads (45%) | catalogued as COSV51562087; called by muse, mutect2, varscan2
- AGT | c.76G>T p.A26S | Missense Mutation (SNP) | VAF 264/539 reads (49%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.469); catalogued as COSV100794497; called by muse, mutect2, varscan2
- AHDC1 | c.4424G>A p.R1475H | Missense Mutation (SNP) | VAF 328/604 reads (54%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.725); catalogued as rs746396362; called by muse, mutect2, varscan2
- AHNAK2 | c.16031C>T p.T5344I | Missense Mutation (SNP) | VAF 47/295 reads (16%) | SIFT tolerated (0.1); PolyPhen benign (0.167); catalogued as rs1028318792; called by muse, mutect2, varscan2
- AHRR | c.325G>A p.V109M | Missense Mutation (SNP) | VAF 162/360 reads (45%) | SIFT tolerated (0.1); PolyPhen benign (0.38); catalogued as rs202003342; called by muse, mutect2, varscan2
- ALKBH4 | c.199G>A p.A67T | Missense Mutation (SNP) | VAF 256/533 reads (48%) | SIFT tolerated (0.08); PolyPhen benign (0.022); catalogued as rs1272307282; called by muse, mutect2, varscan2
- ANKFY1 | c.2237G>A p.R746H (on ENST00000341657 / NM_001330063.2; = p.R747H on NM_016376.5) | Missense Mutation (SNP) | VAF 137/268 reads (51%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.989); catalogued as rs762073269, COSV58918602, COSV58920120; called by muse, mutect2, varscan2
- ANKRD30B | c.1258C>A p.L420I | Missense Mutation (SNP) | VAF 93/178 reads (52%) | SIFT tolerated (0.14); PolyPhen benign (0.427); catalogued as COSV62825843; called by muse, mutect2, varscan2
- ANKUB1 | c.647C>T p.A216V | Missense Mutation (SNP) | VAF 211/444 reads (48%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as rs774131451, COSV67167718; called by muse, mutect2, varscan2
- ANO2 | c.98G>A p.C33Y (on ENST00000356134 / NM_001278597.3; = p.C37Y on NM_001278596.3) | Missense Mutation (SNP) | VAF 167/552 reads (30%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); catalogued as rs754768681; called by muse, mutect2, varscan2
- ANO8 | c.1087del p.L363Cfs*24 | Frame Shift Del (DEL) | VAF 232/620 reads (37%) | catalogued as COSV50178856; called by mutect2, pindel, varscan2
- ANTXR2 | c.955A>T p.I319F | Missense Mutation (SNP) | VAF 103/222 reads (46%) | SIFT tolerated (0.36); PolyPhen benign (0); catalogued as rs1329770281; called by muse, mutect2, varscan2
- APC | c.262C>T p.R88W | Missense Mutation (SNP) | VAF 134/285 reads (47%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.976); catalogued as rs746592911, COSV57336720; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- APCDD1 | c.571C>T p.R191* | Nonsense Mutation (SNP) | VAF 566/879 reads (64%) | catalogued as rs766947286, COSV62372295; called by muse, mutect2, varscan2
- ARHGAP44 | c.520G>A p.A174T | Missense Mutation (SNP) | VAF 96/210 reads (46%) | SIFT tolerated (0.16); PolyPhen benign (0.158); catalogued as rs780981692; called by muse, mutect2, varscan2
- ARHGAP6 | c.1858G>T p.D620Y | Missense Mutation (SNP) | VAF 20/478 reads (4%) | SIFT deleterious (0); PolyPhen possibly damaging (0.765); catalogued as COSV100273134, COSV57302366; called by muse, mutect2
- ARHGEF39 | c.631C>T p.Q211* | Nonsense Mutation (SNP) | VAF 14/243 reads (6%) | catalogued as rs1458213591; called by muse, mutect2
- ARID1A | c.3404C>A p.P1135H | Missense Mutation (SNP) | VAF 145/286 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV61375272; called by muse, mutect2, varscan2
- ARID1A | c.3977del p.P1326Rfs*155 | Frame Shift Del (DEL) | VAF 150/410 reads (37%) | catalogued as COSV61372705; called by mutect2, varscan2
- ARID2 | c.1295C>T p.A432V | Missense Mutation (SNP) | VAF 24/447 reads (5%) | SIFT tolerated (0.47); PolyPhen benign (0.217); catalogued as rs1373868237; called by muse, mutect2
- ARRDC1 | c.1064C>T p.A355V | Missense Mutation (SNP) | VAF 393/393 reads (100%) | SIFT tolerated (0.19); PolyPhen benign (0.005); catalogued as rs1388907024; called by muse, mutect2, varscan2
- ARRDC2 | c.235G>A p.V79M | Missense Mutation (SNP) | VAF 305/669 reads (46%) | SIFT tolerated (0.14); PolyPhen benign (0.027); catalogued as rs1488152915; called by muse, mutect2, varscan2
- ASB14 | c.371dup p.L124Ffs*24 (on ENST00000389601; = p.L123Ffs*24 on NM_001142733.3) | Frame Shift Ins (INS) | VAF 48/206 reads (23%) | catalogued as rs770471078; called by mutect2, varscan2
- ATAD3A | c.1541G>A p.R514H | Missense Mutation (SNP) | VAF 209/440 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs867354699, COSV59232181; called by muse, mutect2, varscan2
- ATF5 | c.255del p.G86Afs*32 | Frame Shift Del (DEL) | VAF 116/352 reads (33%) | catalogued as rs766479650; called by mutect2, varscan2
- ATM | c.8762C>T p.T2921M | Missense Mutation (SNP) | VAF 117/238 reads (49%) | SIFT deleterious (0); PolyPhen possibly damaging (0.766); catalogued as rs730881329, COSV53726751; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- ATP1A3 | c.2687G>A p.R896H (on ENST00000545399 / NM_001256214.2; = p.R883H on NM_152296.5) | Missense Mutation (SNP) | VAF 194/422 reads (46%) | SIFT tolerated (0.18); PolyPhen benign (0.05); catalogued as rs782627825, COSV100132518; called by muse, mutect2, varscan2
- ATP7B | c.1829C>T p.P610L | Missense Mutation (SNP) | VAF 103/331 reads (31%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.635); catalogued as rs368381292; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- ATR | c.2320del p.I774Yfs*5 | Frame Shift Del (DEL) | VAF 80/154 reads (52%) | catalogued as rs757500301, CD112378; ClinVar: not provided; called by mutect2, varscan2
- B3GLCT | c.1129C>T p.R377C | Missense Mutation (SNP) | VAF 154/305 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs758647803, COSV58453711; called by muse, mutect2, varscan2
- B4GALT2 | c.21del p.T8Rfs*102 | Frame Shift Del (DEL) | VAF 188/747 reads (25%) | catalogued as rs759490732, COSV99356264; called by mutect2, pindel, varscan2
- BBX | c.1061C>T p.A354V | Missense Mutation (SNP) | VAF 90/201 reads (45%) | SIFT tolerated (0.43); PolyPhen benign (0.001); catalogued as rs901386189; called by muse, mutect2, varscan2
- BCAT2 | c.445C>T p.R149C | Missense Mutation (SNP) | VAF 197/450 reads (44%) | SIFT tolerated (0.27); PolyPhen probably damaging (0.979); catalogued as COSV60273040; called by muse, mutect2, varscan2
- BDP1 | c.4309C>T p.R1437* | Nonsense Mutation (SNP) | VAF 185/401 reads (46%) | catalogued as rs777807458; called by muse, mutect2, varscan2
- BPIFB4 | c.730G>A p.G244S | Missense Mutation (SNP) | VAF 486/715 reads (68%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs778947397, COSV64950766; called by muse, mutect2, varscan2
- BUD13 | c.688C>T p.R230* | Nonsense Mutation (SNP) | VAF 59/355 reads (17%) | catalogued as rs550302672; called by muse, mutect2, varscan2
- C1QC | c.551G>A p.R184H | Missense Mutation (SNP) | VAF 270/577 reads (47%) | SIFT tolerated (0.18); PolyPhen benign (0.021); catalogued as rs753779937; called by muse, mutect2, varscan2
- C1orf122 | c.151C>T p.Q51* | Nonsense Mutation (SNP) | VAF 340/741 reads (46%) | catalogued as COSV65988889; called by muse, varscan2
- C3orf33 | c.633del p.G212Efs*15 (on ENST00000340171 / NM_001308229.2; = p.G169Efs*15 on NM_173657.2) | Frame Shift Del (DEL) | VAF 136/329 reads (41%) | catalogued as rs762988845; called by mutect2, pindel, varscan2
- C5 | c.4323C>T p.A1441= | Splice Region (SNP) | VAF 98/99 reads (99%) | catalogued as rs773359384; called by muse, mutect2, varscan2
- C5orf34 | c.529dup p.T177Nfs*18 | Frame Shift Ins (INS) | VAF 76/448 reads (17%) | catalogued as rs751673244; called by mutect2, pindel, varscan2
- CACNA1A | c.7145G>A p.R2382Q | Missense Mutation (SNP) | VAF 382/779 reads (49%) | SIFT deleterious (0.05); PolyPhen benign (0.031); catalogued as rs1374236989; called by muse, varscan2
- CACNA1A | c.2618G>A p.R873Q | Missense Mutation (SNP) | VAF 333/706 reads (47%) | SIFT tolerated (0.22); PolyPhen benign (0.369); catalogued as rs1057518589; ClinVar: uncertain significance; called by muse, varscan2
- CAMSAP2 | c.2447C>T p.A816V (on ENST00000236925 / NM_001297707.2; = p.A805V on NM_203459.3) | Missense Mutation (SNP) | VAF 138/303 reads (46%) | SIFT tolerated (0.3); PolyPhen benign (0.359); catalogued as rs780764806; called by muse, mutect2, varscan2
- CASKIN1 | c.3187C>T p.R1063C | Missense Mutation (SNP) | VAF 432/805 reads (54%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs1350909348; called by muse, mutect2, varscan2
- CASP3 | c.682G>A p.D228N | Missense Mutation (SNP) | VAF 128/274 reads (47%) | SIFT tolerated (0.14); PolyPhen benign (0.001); catalogued as rs146955836; called by muse, mutect2, varscan2
- CATSPER1 | c.1930G>A p.A644T | Missense Mutation (SNP) | VAF 162/364 reads (45%) | SIFT deleterious (0); PolyPhen possibly damaging (0.576); catalogued as rs766294676; called by muse, mutect2, varscan2
- CBARP | c.16A>G p.T6A (on ENST00000382477; = p.T12A on NM_152769.3) | Missense Mutation (SNP) | VAF 358/782 reads (46%) | SIFT tolerated, low confidence (0.38); PolyPhen benign (0.003); catalogued as rs143196649; called by muse, varscan2
- CBX6 | c.1013C>T p.P338L | Missense Mutation (SNP) | VAF 372/746 reads (50%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0); catalogued as rs745679342; called by muse, mutect2, varscan2
- CCDC105 | c.1168G>A p.A390T | Missense Mutation (SNP) | VAF 183/401 reads (46%) | SIFT deleterious (0.01); PolyPhen benign (0.083); catalogued as rs755625395, COSV99479903; called by muse, mutect2, varscan2
- CCDC148 | c.98G>A p.R33H | Missense Mutation (SNP) | VAF 108/242 reads (45%) | SIFT tolerated (0.62); PolyPhen benign (0); catalogued as rs140798767; called by muse, mutect2, varscan2
- CCDC150 | c.620G>A p.R207H | Missense Mutation (SNP) | VAF 93/248 reads (38%) | SIFT tolerated (0.2); PolyPhen benign (0.005); catalogued as rs761071958, COSV55877654; called by muse, mutect2, varscan2
- CCDC168 | c.3244del p.S1082Vfs*8 | Frame Shift Del (DEL) | VAF 82/219 reads (37%) | catalogued as COSV70555694; called by mutect2, pindel, varscan2
- CD163L1 | c.709C>T p.R237C | Missense Mutation (SNP) | VAF 150/323 reads (46%) | SIFT tolerated (0.2); PolyPhen possibly damaging (0.469); catalogued as COSV58020915; called by muse, mutect2, varscan2
- CDC14A | c.375del p.Y126Ifs*64 | Frame Shift Del (DEL) | VAF 111/279 reads (40%) | catalogued as rs773911500; called by mutect2, pindel, varscan2
- CDH13 | c.725G>A p.R242Q | Missense Mutation (SNP) | VAF 174/356 reads (49%) | SIFT deleterious (0); PolyPhen possibly damaging (0.488); catalogued as rs1193690872, COSV51786661, COSV51799691; called by muse, mutect2, varscan2
- CDH24 | c.771dup p.K258Qfs*48 | Frame Shift Ins (INS) | VAF 164/378 reads (43%) | catalogued as rs753422808; called by mutect2, varscan2
- CDHR2 | c.1480G>A p.A494T | Missense Mutation (SNP) | VAF 211/418 reads (50%) | SIFT deleterious (0.03); PolyPhen benign (0.017); catalogued as rs1392873867, COSV99991771; called by muse, varscan2
- CDK10 | c.572C>T p.P191L (on ENST00000353379 / NM_052988.5; = p.P120L on NM_052987.4) | Missense Mutation (SNP) | VAF 16/540 reads (3%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.934); catalogued as rs1270154501, COSV57048528; called by muse, mutect2
- CDKAL1 | c.469G>A p.V157I | Missense Mutation (SNP) | VAF 97/97 reads (100%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.638); catalogued as rs1188216906; called by muse, varscan2
- CEP68 | c.1282G>T p.G428C | Missense Mutation (SNP) | VAF 213/422 reads (50%) | SIFT deleterious (0); PolyPhen benign (0.177); catalogued as COSV53125736; called by muse, mutect2, varscan2
- CFAP47 | c.2761C>T p.Q921* | Nonsense Mutation (SNP) | VAF 187/387 reads (48%) | catalogued as COSV52885562, COSV99934429; called by muse, mutect2, varscan2
- CHD5 | c.692dup p.Q232Afs*61 | Frame Shift Ins (INS) | VAF 330/642 reads (51%) | catalogued as rs766709340; called by mutect2, varscan2
- CHD8 | c.2098C>T p.R700C (on ENST00000646647 / NM_001170629.2; = p.R421C on NM_020920.4) | Missense Mutation (SNP) | VAF 116/263 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs868527880, COSV67869986; called by muse, mutect2, varscan2
- CHDH | c.1210C>T p.P404S | Missense Mutation (SNP) | VAF 15/313 reads (5%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as COSV59455592; called by muse, mutect2
- CHGA | c.5G>A p.R2H | Missense Mutation (SNP) | VAF 256/491 reads (52%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.454); catalogued as rs971618106; called by muse, mutect2, varscan2
- CKAP2 | c.1879C>T p.R627C (on ENST00000378037 / NM_001098525.2; = p.R626C on NM_018204.5) | Missense Mutation (SNP) | VAF 98/237 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as rs748867286, COSV51623279; called by muse, mutect2, varscan2
- CLDN10 | c.95C>T p.T32M | Missense Mutation (SNP) | VAF 190/406 reads (47%) | SIFT deleterious (0); PolyPhen possibly damaging (0.86); catalogued as rs1419354135, COSV65300236; called by muse, mutect2, varscan2
- CLDN6 | c.625C>T p.R209W | Missense Mutation (SNP) | VAF 216/452 reads (48%) | SIFT deleterious (0.02); PolyPhen benign (0.17); catalogued as rs535126754; called by muse, varscan2
- CLDN6 | c.242G>A p.R81H | Missense Mutation (SNP) | VAF 249/506 reads (49%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as rs528018513; called by muse, mutect2, varscan2
- CLDN9 | c.537dup p.L180Afs*104 | Frame Shift Ins (INS) | VAF 282/745 reads (38%) | catalogued as rs763852712; called by mutect2, pindel, varscan2
- CLEC18C | c.208C>T p.R70W | Missense Mutation (SNP) | VAF 158/468 reads (34%) | SIFT deleterious (0); PolyPhen possibly damaging (0.828); catalogued as rs1042778645; called by muse, varscan2
- CLIP2 | c.2278G>A p.E760K | Missense Mutation (SNP) | VAF 242/464 reads (52%) | SIFT tolerated (0.05); PolyPhen benign (0.137); catalogued as rs374499437; called by muse, mutect2, varscan2
- CMTM1 | c.128A>G p.N43S (on ENST00000457188 / NM_181269.3; = p.N160S on NM_052999.4) | Missense Mutation (SNP) | VAF 87/333 reads (26%) | SIFT tolerated (0.59); PolyPhen benign (0.179); catalogued as rs753161061; called by muse, mutect2, varscan2
- CNGA2 | c.784C>T p.R262W | Missense Mutation (SNP) | VAF 308/669 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as rs747754116, COSV61704268, COSV61704381; called by muse, mutect2, varscan2
- COL20A1 | c.1094G>A p.R365Q | Missense Mutation (SNP) | VAF 171/676 reads (25%) | SIFT tolerated (0.57); PolyPhen benign (0.02); catalogued as rs1255629105; called by muse, mutect2, varscan2
- COL4A6 | c.1830del p.G611Afs*127 | Frame Shift Del (DEL) | VAF 299/716 reads (42%) | catalogued as rs771066852; called by mutect2, pindel, varscan2
- COL9A2 | c.1242dup p.G415Rfs*29 | Frame Shift Ins (INS) | VAF 202/428 reads (47%) | catalogued as rs756694568; ClinVar: uncertain significance; called by mutect2, varscan2
- CRACR2B | c.775C>T p.R259W | Missense Mutation (SNP) | VAF 311/657 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV58990733; called by muse, mutect2, varscan2
- CREB3L4 | c.677G>A p.R226H | Missense Mutation (SNP) | VAF 42/276 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as rs141048946; called by muse, varscan2
- CREM | c.614G>A p.G205D (on ENST00000429130; = p.G172D on NM_181571.3) | Missense Mutation (SNP) | VAF 71/318 reads (22%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.52); catalogued as rs199612996; called by muse, mutect2, varscan2
- CROCC2 | c.1882G>A p.A628T | Missense Mutation (SNP) | VAF 201/520 reads (39%) | SIFT tolerated (0.4); PolyPhen benign (0.338); catalogued as rs568734799; called by muse, mutect2, varscan2
- CRP | c.466G>A p.E156K | Missense Mutation (SNP) | VAF 291/561 reads (52%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.985); catalogued as rs748954737, COSV54814395; called by muse, mutect2, varscan2
- CSMD2 | c.2104C>T p.R702W | Missense Mutation (SNP) | VAF 41/470 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs756380964; called by muse, mutect2
- CTNNBL1 | c.125G>A p.R42Q | Missense Mutation (SNP) | VAF 188/602 reads (31%) | SIFT tolerated (0.56); PolyPhen benign (0.012); catalogued as rs764060163, COSV63743564, COSV63745558; called by muse, mutect2, varscan2
- CX3CL1 | c.400G>A p.E134K | Missense Mutation (SNP) | VAF 229/473 reads (48%) | SIFT tolerated (0.1); PolyPhen benign (0.091); catalogued as rs558560542, COSV99136284; called by muse, mutect2, varscan2
- CYP4F2 | c.437G>A p.R146H | Missense Mutation (SNP) | VAF 178/404 reads (44%) | SIFT tolerated (0.25); PolyPhen benign (0.104); catalogued as rs61755872; called by muse, mutect2, varscan2
- CYP4F22 | c.50C>T p.T17M | Missense Mutation (SNP) | VAF 258/535 reads (48%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.732); catalogued as rs773295754, COSV99512903; called by muse, mutect2, varscan2
- CYP7B1 | c.662A>G p.D221G | Missense Mutation (SNP) | VAF 96/185 reads (52%) | SIFT tolerated (0.34); PolyPhen benign (0.012); catalogued as COSV100040356; called by muse, mutect2, varscan2
- DAND5 | c.434G>A p.C145Y | Missense Mutation (SNP) | VAF 247/532 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as rs376389047; called by muse, mutect2, varscan2
- DBH | c.1778C>A p.T593N | Missense Mutation (SNP) | VAF 276/276 reads (100%) | SIFT tolerated (0.4); PolyPhen benign (0.023); catalogued as rs551844036, COSV67549641; called by muse, mutect2, varscan2
- DCAF8L2 | c.232G>A p.A78T | Missense Mutation (SNP) | VAF 204/479 reads (43%) | SIFT tolerated (0.09); PolyPhen benign (0.007); catalogued as rs1163117597; called by muse, varscan2
- DGAT2L6 | c.694A>G p.N232D | Missense Mutation (SNP) | VAF 186/411 reads (45%) | SIFT tolerated (0.64); PolyPhen benign (0.01); catalogued as rs142841201; called by muse, mutect2, varscan2
- DGKH | c.2065C>T p.R689W | Missense Mutation (SNP) | VAF 169/314 reads (54%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.462); catalogued as rs764666256; called by muse, mutect2, varscan2
- DNAH9 | c.11733G>T p.K3911N | Missense Mutation (SNP) | VAF 117/236 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV52346618; called by muse, mutect2, varscan2
- DNAJC10 | c.1911del p.P639Qfs*22 | Frame Shift Del (DEL) | VAF 90/247 reads (36%) | catalogued as rs1283431287; called by mutect2, pindel, varscan2
- DNHD1 | c.5981C>T p.A1994V | Missense Mutation (SNP) | VAF 197/388 reads (51%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.616); catalogued as rs777555724; called by muse, mutect2, varscan2
- DOCK10 | c.1122del p.D375Ifs*8 | Frame Shift Del (DEL) | VAF 108/205 reads (53%) | catalogued as rs750262341; called by mutect2, varscan2
- DOCK11 | c.3997G>A p.A1333T | Missense Mutation (SNP) | VAF 16/349 reads (5%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.49); catalogued as rs1412531892; called by muse, mutect2
- DOHH | c.112G>A p.G38S | Missense Mutation (SNP) | VAF 344/755 reads (46%) | SIFT tolerated (0.68); PolyPhen benign (0.003); catalogued as COSV99170993; called by muse, mutect2, varscan2
- DPF1 | c.800C>T p.T267M | Missense Mutation (SNP) | VAF 159/344 reads (46%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.802); catalogued as rs1004539756; called by muse, mutect2, varscan2
- DPPA3 | c.466C>T p.P156S | Missense Mutation (SNP) | VAF 153/288 reads (53%) | SIFT tolerated (0.39); PolyPhen benign (0.005); catalogued as rs775271861, COSV61503365; called by muse, mutect2, varscan2
- DPYSL4 | c.1145C>T p.A382V | Missense Mutation (SNP) | VAF 165/346 reads (48%) | SIFT deleterious (0); PolyPhen possibly damaging (0.807); catalogued as rs1378531905, COSV58307562; called by muse, mutect2, varscan2
- DRGX | c.641G>A p.R214H | Missense Mutation (SNP) | VAF 182/617 reads (29%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.998); catalogued as rs201807477, COSV65137865; called by muse, mutect2, varscan2
- DSCAML1 | c.4034C>T p.A1345V (on ENST00000321322; = p.A1285V on NM_020693.4) | Missense Mutation (SNP) | VAF 28/373 reads (8%) | SIFT tolerated (0.33); PolyPhen benign (0.007); catalogued as COSV100354513; called by muse, mutect2
- DSEL | c.1699G>A p.V567M | Missense Mutation (SNP) | VAF 252/253 reads (100%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.812); catalogued as rs777465144; called by muse, mutect2, varscan2
- ECI1 | c.707C>T p.A236V | Missense Mutation (SNP) | VAF 270/513 reads (53%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.845); catalogued as rs758776830, COSV100066451; called by muse, mutect2, varscan2
- EIF3A | c.2369G>T p.R790L | Missense Mutation (SNP) | VAF 174/367 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as rs772554138, COSV64960718; called by muse, mutect2, varscan2
- EP400 | c.2011G>A p.A671T | Missense Mutation (SNP) | VAF 301/611 reads (49%) | SIFT tolerated, low confidence (0.17); PolyPhen benign (0); catalogued as rs146452426; called by muse, mutect2, varscan2
- EPB41L2 | c.1354C>T p.R452C | Missense Mutation (SNP) | VAF 141/141 reads (100%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs765521376, COSV61356920; called by muse, mutect2, varscan2
- EPB41L3 | c.2585G>A p.R862H | Missense Mutation (SNP) | VAF 225/439 reads (51%) | SIFT tolerated (0.52); PolyPhen benign (0); catalogued as rs200869858; called by muse, mutect2, varscan2
- EPG5 | c.4361G>A p.R1454H | Missense Mutation (SNP) | VAF 172/172 reads (100%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.966); catalogued as rs766875773, COSV56348725; called by muse, mutect2, varscan2
- EPHA1 | c.991G>T p.G331C | Missense Mutation (SNP) | VAF 150/281 reads (53%) | SIFT deleterious (0); PolyPhen benign (0.41); catalogued as COSV51976747; called by muse, mutect2, varscan2
- EPS15L1 | c.2227G>A p.D743N | Missense Mutation (SNP) | VAF 18/496 reads (4%) | SIFT deleterious (0); PolyPhen possibly damaging (0.564); catalogued as rs1355642969; called by muse, mutect2
- ERC1 | c.38C>T p.P13L | Missense Mutation (SNP) | VAF 136/321 reads (42%) | SIFT deleterious (0.05); PolyPhen benign (0.017); catalogued as rs771123374; called by muse, mutect2, varscan2
- ERGIC3 | c.717C>T p.N239= | Splice Region (SNP) | VAF 232/645 reads (36%) | catalogued as rs201199310; called by muse, mutect2, varscan2
- ESD | c.781A>G p.S261G | Missense Mutation (SNP) | VAF 85/182 reads (47%) | SIFT tolerated (0.26); PolyPhen benign (0.001); catalogued as rs1270161272; called by muse, mutect2, varscan2
- ESYT1 | c.2783G>A p.S928N | Missense Mutation (SNP) | VAF 24/583 reads (4%) | SIFT tolerated (0.14); PolyPhen benign (0.014); catalogued as COSV57271645; called by muse, mutect2
- EYA2 | c.254C>T p.T85I | Missense Mutation (SNP) | VAF 33/730 reads (5%) | SIFT deleterious (0); PolyPhen possibly damaging (0.576); catalogued as rs1568718555; called by muse, mutect2
- FAHD2A | c.842del p.P281Qfs*26 | Frame Shift Del (DEL) | VAF 167/346 reads (48%) | catalogued as rs766589051; called by mutect2, varscan2
- FAM222A | c.968G>A p.R323Q | Missense Mutation (SNP) | VAF 341/689 reads (49%) | SIFT tolerated (0.07); PolyPhen benign (0.001); catalogued as rs376914566; called by muse, mutect2, varscan2
- FAM91A1 | c.2338G>A p.A780T | Missense Mutation (SNP) | VAF 95/218 reads (44%) | SIFT tolerated (0.59); PolyPhen benign (0); catalogued as rs769171490, COSV58235667; called by muse, mutect2, varscan2
- FAM98A | c.1087C>T p.R363C | Missense Mutation (SNP) | VAF 69/536 reads (13%) | SIFT deleterious (0.03); PolyPhen benign (0.001); catalogued as rs1407631434, COSV53211134; called by muse, mutect2, varscan2
- FBLN2 | c.3314G>A p.R1105H | Missense Mutation (SNP) | VAF 266/584 reads (46%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs369694803; called by muse, varscan2
- FBXO17 | c.205G>A p.A69T | Missense Mutation (SNP) | VAF 122/709 reads (17%) | SIFT tolerated (0.19); PolyPhen benign (0.001); catalogued as rs1391048820; called by muse, mutect2, varscan2
- FCRLA | c.775G>A p.G259R (on ENST00000367959; = p.G236R on NM_032738.4) | Missense Mutation (SNP) | VAF 201/438 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs140120225; called by muse, mutect2, varscan2
- FGFBP2 | c.181G>A p.V61I | Missense Mutation (SNP) | VAF 234/478 reads (49%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs1488358811; called by muse, mutect2, varscan2
- FIGNL1 | c.514C>T p.R172W | Missense Mutation (SNP) | VAF 175/353 reads (50%) | SIFT tolerated (0.06); PolyPhen benign (0.001); catalogued as rs140068296; called by muse, mutect2, varscan2
- FLT3 | c.2659A>G p.N887D | Missense Mutation (SNP) | VAF 120/269 reads (45%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.78); catalogued as COSV54060725; called by muse, mutect2, varscan2
- FLT4 | c.3527G>T p.R1176M | Missense Mutation (SNP) | VAF 237/502 reads (47%) | SIFT deleterious (0.01); PolyPhen benign (0.375); catalogued as COSV56103230; called by muse, mutect2, varscan2
- FLT4 | c.2228C>T p.A743V | Missense Mutation (SNP) | VAF 328/638 reads (51%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.952); catalogued as COSV56098861; called by muse, mutect2, varscan2
- FMN2 | c.2377C>T p.R793* | Nonsense Mutation (SNP) | VAF 250/521 reads (48%) | catalogued as rs780928554, COSV60425069; called by muse, mutect2, varscan2
- FPR1 | c.349G>A p.A117T | Missense Mutation (SNP) | VAF 256/510 reads (50%) | SIFT tolerated (0.54); PolyPhen benign (0.019); catalogued as rs547228145, COSV59053059; called by muse, mutect2
- FRMPD4 | c.3313del p.S1105Vfs*3 | Frame Shift Del (DEL) | VAF 231/712 reads (32%) | catalogued as rs35659462; called by pindel, varscan2
- FUZ | c.47C>T p.A16V | Missense Mutation (SNP) | VAF 49/662 reads (7%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.559); catalogued as rs1006344377; called by muse, mutect2
- GAB4 | c.153del p.E52Rfs*4 | Frame Shift Del (DEL) | VAF 204/481 reads (42%) | catalogued as rs764879401, COSV68754102; called by mutect2, pindel, varscan2
- GABRD | c.98G>A p.G33D | Missense Mutation (SNP) | VAF 18/494 reads (4%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV66081499; called by muse, mutect2
- GAD2 | c.830C>T p.T277M | Missense Mutation (SNP) | VAF 135/280 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs753672041, COSV52161355, COSV99035167; called by muse, mutect2, varscan2
- GALNT2 | c.80G>A p.G27D | Missense Mutation (SNP) | VAF 390/767 reads (51%) | SIFT tolerated (0.47); PolyPhen benign (0.077); catalogued as rs1327732533, COSV64192684; called by muse, mutect2, varscan2
- GANAB | c.2050C>T p.R684* | Nonsense Mutation (SNP) | VAF 58/505 reads (11%) | catalogued as COSV100647734; called by muse, mutect2, varscan2
- GAPVD1 | c.1304T>C p.M435T | Missense Mutation (SNP) | VAF 184/185 reads (99%) | SIFT tolerated (0.45); PolyPhen benign (0.018); catalogued as COSV52920608; called by muse, mutect2, varscan2
- GATB | c.19C>G p.R7G | Missense Mutation (SNP) | VAF 208/455 reads (46%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.049); catalogued as COSV56130377; called by muse, mutect2, varscan2
- GEMIN5 | c.2176del p.S726Vfs*24 | Frame Shift Del (DEL) | VAF 109/293 reads (37%) | catalogued as COSV53564949; called by mutect2, pindel, varscan2
- GGT1 | c.1489C>T p.R497W | Missense Mutation (SNP) | VAF 141/493 reads (29%) | SIFT deleterious (0); PolyPhen benign (0.01); catalogued as rs45445196; called by muse, mutect2, varscan2
- GJB4 | c.668G>A p.R223Q | Missense Mutation (SNP) | VAF 234/433 reads (54%) | SIFT tolerated (0.21); PolyPhen benign (0.003); catalogued as rs778397300, COSV58355656, COSV58357162; called by muse, mutect2, varscan2
- GLI2 | c.2033C>T p.T678M (on ENST00000361492 / NM_001374353.1; = p.T695M on NM_005270.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 300/656 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as rs150858529, COSV58042900; called by muse, mutect2, varscan2
- GLIS2 | c.421G>C p.A141P | Missense Mutation (SNP) | VAF 378/771 reads (49%) | SIFT deleterious (0.04); PolyPhen benign (0.005); catalogued as COSV52110075; called by muse, mutect2, varscan2
- GM2A | c.506G>A p.R169H | Missense Mutation (SNP) | VAF 187/412 reads (45%) | SIFT deleterious (0.05); PolyPhen benign (0.044); catalogued as rs104893892, CM930346; called by muse, mutect2, varscan2
- GNRH1 | c.272_274del p.K91del | In Frame Del (DEL) | VAF 81/200 reads (41%) | catalogued as rs762423253; called by pindel, varscan2
- GOLGA6L22 | c.1387C>T p.R463W | Missense Mutation (SNP) | VAF 38/646 reads (6%) | SIFT tolerated (0.14); catalogued as rs1377917573; called by muse, mutect2
- GOLGA6L9 | c.983G>A p.R328H | Missense Mutation (SNP) | VAF 74/1074 reads (7%) | SIFT tolerated (0.52); PolyPhen possibly damaging (0.715); catalogued as rs1411536845; called by muse, mutect2
- GP2 | c.766C>A p.L256M (on ENST00000381362 / NM_001007240.3; = p.L253M on NM_001502.4) | Missense Mutation (SNP) | VAF 236/479 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1390353891, COSV56894286; called by muse, mutect2, varscan2
- GPR148 | c.352C>T p.R118C | Missense Mutation (SNP) | VAF 336/658 reads (51%) | SIFT tolerated (0.27); PolyPhen benign (0.003); catalogued as rs780544205, COSV59307967; called by muse, mutect2, varscan2
- GPR27 | c.833C>T p.T278M | Missense Mutation (SNP) | VAF 187/189 reads (99%) | SIFT tolerated (0.56); PolyPhen benign (0.011); catalogued as rs773053190, COSV55203995; called by muse, mutect2, varscan2
- GPR6 | c.20C>T p.S7L | Missense Mutation (SNP) | VAF 95/282 reads (34%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.006); catalogued as COSV51572014; called by muse, mutect2, varscan2
- GPR65 | c.371del p.F124Sfs*2 | Frame Shift Del (DEL) | VAF 58/360 reads (16%) | catalogued as rs770829884; called by mutect2, varscan2
- GPR84 | c.82del p.V28Wfs*5 | Frame Shift Del (DEL) | VAF 233/654 reads (36%) | catalogued as rs759103894; called by pindel, varscan2
- GRAMD1B | c.2173G>A p.D725N | Missense Mutation (SNP) | VAF 159/379 reads (42%) | SIFT deleterious (0); PolyPhen possibly damaging (0.652); catalogued as COSV59204216, COSV99074529; called by muse, mutect2, varscan2
- GRID1 | c.1693G>A p.V565M | Missense Mutation (SNP) | VAF 142/292 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); catalogued as rs778197505, COSV60021931; called by muse, mutect2, varscan2
- GRID2IP | c.1622C>T p.T541M | Missense Mutation (SNP) | VAF 246/516 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs942337846; called by muse, mutect2, varscan2
- GRIN2A | c.3863G>A p.R1288H | Missense Mutation (SNP) | VAF 129/458 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs778951185, COSV58035660; called by muse, mutect2, varscan2
- GRIN2B | c.2639G>A p.R880H | Missense Mutation (SNP) | VAF 135/387 reads (35%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.871); catalogued as rs904771425, COSV74205198, COSV74206925; called by muse, mutect2, varscan2
- GTF2H1 | c.1495C>T p.R499* | Nonsense Mutation (SNP) | VAF 38/273 reads (14%) | catalogued as rs1455056672, COSV56379748; called by muse, mutect2, varscan2
- GUCY2D | c.3076G>T p.G1026W | Missense Mutation (SNP) | VAF 87/582 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.762); catalogued as COSV54694979; called by muse, mutect2, varscan2
- GUCY2F | c.2237G>A p.R746Q | Missense Mutation (SNP) | VAF 233/497 reads (47%) | SIFT tolerated (0.06); PolyPhen probably damaging (1); catalogued as rs1477248854, COSV54297893; called by muse, mutect2, varscan2
- HAX1 | c.463del p.Q155Nfs*59 | Frame Shift Del (DEL) | VAF 194/469 reads (41%) | catalogued as COSV55172930; called by mutect2, pindel, varscan2
- HDAC7 | c.1577C>T p.S526L (on ENST00000427332; = p.S565L on NM_015401.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 224/443 reads (51%) | SIFT deleterious (0); PolyPhen benign (0.057); catalogued as rs150532318; called by muse, mutect2, varscan2
- HEATR5B | c.5627T>C p.I1876T | Missense Mutation (SNP) | VAF 73/392 reads (19%) | SIFT tolerated (0.78); PolyPhen benign (0.007); catalogued as rs745605612; called by muse, mutect2, varscan2
- HERC1 | c.11230C>T p.R3744W | Missense Mutation (SNP) | VAF 32/461 reads (7%) | SIFT deleterious (0.03); PolyPhen benign (0.438); catalogued as rs529584007, COSV71247061; called by muse, mutect2
- HGFAC | c.1800dup p.P601Afs*20 | Frame Shift Ins (INS) | VAF 220/622 reads (35%) | catalogued as rs770643102; called by mutect2, pindel, varscan2
- HGSNAT | c.693G>A p.W231* | Nonsense Mutation (SNP) | VAF 200/410 reads (49%) | catalogued as COSV65536005; called by muse, mutect2, varscan2
- HIVEP3 | c.1754G>A p.R585Q | Missense Mutation (SNP) | VAF 242/484 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs751390922, COSV56018437; called by muse, mutect2, varscan2
- HMCN1 | c.14536C>T p.P4846S | Missense Mutation (SNP) | VAF 26/474 reads (5%) | SIFT deleterious (0.04); PolyPhen benign (0.239); catalogued as COSV54893251; called by muse, mutect2
- HSD17B14 | c.700G>A p.E234K | Missense Mutation (SNP) | VAF 403/821 reads (49%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.795); catalogued as rs1400589983, COSV99622656; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- HSD3B2 | c.832C>T p.R278C | Missense Mutation (SNP) | VAF 151/330 reads (46%) | SIFT tolerated (0.23); PolyPhen benign (0.009); catalogued as rs587711475; called by muse, mutect2, varscan2
- HSPA12A | c.491A>G p.K164R | Missense Mutation (SNP) | VAF 191/416 reads (46%) | SIFT tolerated (0.23); PolyPhen benign (0.012); catalogued as rs1554881213; called by muse, mutect2, varscan2
- HSPG2 | c.6010C>T p.R2004C | Missense Mutation (SNP) | VAF 226/529 reads (43%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.659); catalogued as rs777591903, COSV101020332, COSV65975083; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- IFFO2 | c.1363G>A p.E455K | Missense Mutation (SNP) | VAF 186/400 reads (47%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.993); catalogued as rs1274576588, COSV100841950; called by muse, mutect2, varscan2
- IFI16 | c.1873A>G p.T625A (on ENST00000295809 / NM_001364867.2; = p.T569A on NM_005531.3 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 152/291 reads (52%) | SIFT tolerated (0.23); PolyPhen benign (0.018); catalogued as COSV99857154; called by muse, mutect2, varscan2
- IGF2 | c.686del p.P229Qfs*27 (on ENST00000434045 / NM_001127598.3; = p.P173Qfs*27 on NM_000612.6) | Frame Shift Del (DEL) | VAF 236/662 reads (36%) | catalogued as rs755455183; ClinVar: uncertain significance; called by pindel, varscan2
- IL12RB2 | c.766C>T p.R256* | Nonsense Mutation (SNP) | VAF 135/308 reads (44%) | catalogued as rs771578695, COSV52027175; called by muse, mutect2, varscan2
- IL1RAPL2 | c.691G>A p.V231I | Missense Mutation (SNP) | VAF 102/215 reads (47%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.527); catalogued as rs780226679; called by muse, mutect2, varscan2
- IL7R | c.575A>G p.Q192R | Missense Mutation (SNP) | VAF 115/283 reads (41%) | SIFT tolerated (0.79); PolyPhen benign (0.039); catalogued as rs1345734622; called by muse, mutect2, varscan2
- ILK | c.211del p.L71Cfs*26 | Frame Shift Del (DEL) | VAF 185/451 reads (41%) | catalogued as rs776120061, COSV54448886; ClinVar: uncertain significance; called by mutect2, pindel, varscan2
- IMMP2L | c.374A>G p.H125R | Missense Mutation (SNP) | VAF 121/291 reads (42%) | SIFT tolerated (0.5); PolyPhen probably damaging (0.966); catalogued as rs1198333573; called by muse, mutect2, varscan2
- INHBC | c.973del p.L325Cfs*21 | Frame Shift Del (DEL) | VAF 53/416 reads (13%) | catalogued as rs1330733432; called by mutect2, pindel, varscan2
- INPP5F | c.631dup p.W211Lfs*3 | Frame Shift Ins (INS) | VAF 95/232 reads (41%) | catalogued as rs768918635; called by mutect2, varscan2
- IQCE | c.872G>A p.G291D | Missense Mutation (SNP) | VAF 208/425 reads (49%) | SIFT tolerated (0.08); PolyPhen benign (0.078); catalogued as rs774115233; called by muse, mutect2, varscan2
- IRS4 | c.448C>A p.L150I | Missense Mutation (SNP) | VAF 289/608 reads (48%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.991); catalogued as COSV64535612; called by muse, mutect2, varscan2
- ISX | c.335G>A p.R112H | Missense Mutation (SNP) | VAF 158/349 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs147806898; called by muse, mutect2, varscan2
- ITIH6 | c.1202C>T p.T401M | Missense Mutation (SNP) | VAF 62/710 reads (9%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.996); catalogued as rs748734617, COSV54486031; called by muse, mutect2
- ITPR3 | c.5800G>A p.V1934M | Missense Mutation (SNP) | VAF 271/272 reads (100%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs778613128, COSV65410890; called by muse, mutect2, varscan2
- ITSN2 | c.4720C>T p.H1574Y | Missense Mutation (SNP) | VAF 33/392 reads (8%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.932); catalogued as rs1247351715; called by muse, mutect2
- JAK3 | c.1229G>A p.S410N | Missense Mutation (SNP) | VAF 198/402 reads (49%) | SIFT tolerated (0.56); PolyPhen benign (0); catalogued as COSV71687414; called by muse, mutect2, varscan2
- JMJD7-PLA2G4B | c.755G>A p.R252H | Missense Mutation (SNP) | VAF 226/455 reads (50%) | SIFT deleterious (0.05); PolyPhen benign (0.365); catalogued as rs569293395, COSV59825406; called by muse, mutect2, varscan2
- KATNBL1 | c.433del p.S145Lfs*19 | Frame Shift Del (DEL) | VAF 42/207 reads (20%) | catalogued as rs1206265094; called by mutect2, pindel, varscan2
- KCNB2 | c.155C>T p.T52M | Missense Mutation (SNP) | VAF 195/395 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs1225497498, COSV73049361; called by muse, mutect2, varscan2
- KCNH8 | c.2210C>T p.S737L | Missense Mutation (SNP) | VAF 146/316 reads (46%) | SIFT tolerated (0.42); PolyPhen benign (0.039); catalogued as rs1431768344, COSV60460323; called by muse, mutect2, varscan2
- KCNK12 | c.1211C>T p.T404M | Missense Mutation (SNP) | VAF 79/874 reads (9%) | SIFT deleterious (0.02); PolyPhen benign (0.416); catalogued as COSV59946169; called by muse, mutect2
- KDM2B | c.77del p.K26Rfs*81 | Frame Shift Del (DEL) | VAF 221/506 reads (44%) | catalogued as rs782541016; called by mutect2, pindel, varscan2
- KDM5A | c.2737G>T p.D913Y | Missense Mutation (SNP) | VAF 28/443 reads (6%) | SIFT deleterious (0); PolyPhen benign (0.079); catalogued as COSV66991434; called by muse, mutect2
- KIAA0100 | c.4171G>A p.V1391I | Missense Mutation (SNP) | VAF 221/453 reads (49%) | SIFT tolerated (0.44); PolyPhen probably damaging (0.969); catalogued as rs757697591, COSV66492040; called by muse, mutect2, varscan2
- KIAA1210 | c.17C>T p.T6M | Missense Mutation (SNP) | VAF 222/467 reads (48%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.362); catalogued as rs368835636, COSV68178005; called by muse, mutect2, varscan2
- KIAA1217 | c.4748C>T p.A1583V | Missense Mutation (SNP) | VAF 234/517 reads (45%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.998); catalogued as rs773862720; called by muse, mutect2
- KIF18B | c.2452+8G>A | Splice Region (SNP) | VAF 137/263 reads (52%) | catalogued as rs530427949, COSV100192338; called by muse, mutect2, varscan2
- KIF26B | c.6010C>T p.R2004* | Nonsense Mutation (SNP) | VAF 198/463 reads (43%) | catalogued as COSV63653044; called by muse, mutect2
- KIF7 | c.2185C>T p.R729C | Missense Mutation (SNP) | VAF 138/300 reads (46%) | SIFT deleterious (0); PolyPhen possibly damaging (0.649); catalogued as rs763584371, COSV67997530; called by muse, mutect2, varscan2
- KLHL33 | c.706C>T p.R236W | Missense Mutation (SNP) | VAF 310/622 reads (50%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.895); catalogued as rs996119781, COSV60727732; called by muse, mutect2, varscan2
- KMT2C | c.2711G>A p.R904Q | Missense Mutation (SNP) | VAF 104/292 reads (36%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.978); catalogued as rs764909368, COSV51493691; called by muse, varscan2
- KRT14 | c.200del p.G67Afs*51 | Frame Shift Del (DEL) | VAF 239/412 reads (58%) | catalogued as rs769596857; called by pindel, varscan2
- LAMC2 | c.2306T>C p.V769A | Missense Mutation (SNP) | VAF 130/244 reads (53%) | SIFT tolerated (0.86); PolyPhen benign (0); catalogued as rs74445945; called by muse, mutect2, varscan2
- LCMT2 | c.1033G>A p.V345I | Missense Mutation (SNP) | VAF 246/483 reads (51%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.565); catalogued as rs903537988; called by muse, mutect2, varscan2
- LCT | c.2945G>A p.R982Q | Missense Mutation (SNP) | VAF 211/368 reads (57%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV51544049; called by muse, mutect2, varscan2
- LDHD | c.1361G>A p.R454Q | Missense Mutation (SNP) | VAF 245/485 reads (51%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.663); catalogued as rs139673012; called by muse, mutect2, varscan2
- LDLRAD1 | c.445del p.D149Tfs*6 | Frame Shift Del (DEL) | VAF 141/361 reads (39%) | catalogued as COSV64956147; called by mutect2, pindel, varscan2
- LGALS9 | c.32T>C p.L11P | Missense Mutation (SNP) | VAF 17/353 reads (5%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.715); catalogued as COSV100119496; called by muse, mutect2
- LGI2 | c.1013C>T p.T338M | Missense Mutation (SNP) | VAF 233/490 reads (48%) | SIFT tolerated (0.28); PolyPhen benign (0.042); catalogued as rs144272338; called by muse, mutect2, varscan2
- LMTK3 | c.2182G>C p.A728P | Missense Mutation (SNP) | VAF 149/330 reads (45%) | SIFT deleterious, low confidence (0.05); PolyPhen possibly damaging (0.5); catalogued as rs1465136841; called by muse, varscan2
- LRP2 | c.13588G>A p.D4530N | Missense Mutation (SNP) | VAF 61/399 reads (15%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.722); catalogued as rs749693268; called by muse, varscan2
- LRRC38 | c.650G>A p.C217Y | Missense Mutation (SNP) | VAF 36/297 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV101065851; called by muse, mutect2, varscan2
- LTBP4 | c.4361C>T p.P1454L (on ENST00000308370 / NM_001042544.1; = p.P1417L on NM_003573.2) | Missense Mutation (SNP) | VAF 366/766 reads (48%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.467); catalogued as rs190277382, COSV99180973; called by muse, mutect2, varscan2
- MAGEB17 | c.28C>T p.R10C | Missense Mutation (SNP) | VAF 229/483 reads (47%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.866); catalogued as rs1250947733, COSV61557263; called by muse, mutect2, varscan2
- MAP1A | c.2636G>A p.R879H | Missense Mutation (SNP) | VAF 247/487 reads (51%) | SIFT deleterious (0.02); PolyPhen benign (0.029); catalogued as rs192228146; called by muse, mutect2, varscan2
- MAP2K7 | c.875del p.P292Qfs*119 | Frame Shift Del (DEL) | VAF 241/555 reads (43%) | catalogued as COSV67608111; called by mutect2, pindel, varscan2
- MAPK12 | c.1075del p.A359Pfs*19 | Frame Shift Del (DEL) | VAF 172/443 reads (39%) | catalogued as rs1184072475; called by mutect2, pindel, varscan2
- MAPK3 | c.32del p.G11Afs*21 | Frame Shift Del (DEL) | VAF 192/430 reads (45%) | catalogued as COSV53772256; called by mutect2, varscan2
- MCM10 | c.118G>A p.D40N | Missense Mutation (SNP) | VAF 193/407 reads (47%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.967); catalogued as rs1018504619; called by muse, mutect2, varscan2
- MCM7 | c.1114C>T p.R372W | Missense Mutation (SNP) | VAF 118/336 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1332080071; called by muse, mutect2, varscan2
- MED22 | c.521C>T p.P174L | Missense Mutation (SNP) | VAF 12/347 reads (3%) | SIFT tolerated, low confidence (0.24); PolyPhen benign (0.043); catalogued as rs145949119; called by muse, mutect2
- MED25 | c.602del p.P201Rfs*13 | Frame Shift Del (DEL) | VAF 244/612 reads (40%) | catalogued as rs748546983; ClinVar: uncertain significance; called by mutect2, pindel, varscan2
- MIB2 | c.494G>A p.R165H | Missense Mutation (SNP) | VAF 397/819 reads (48%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.97); catalogued as rs759149248; called by muse, mutect2, varscan2
- MLLT1 | c.617G>A p.R206H | Missense Mutation (SNP) | VAF 253/551 reads (46%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.991); catalogued as rs759257032, COSV53129465, COSV99398183; called by muse, mutect2, varscan2
- MMACHC | c.547_548del p.V183Tfs*5 | Frame Shift Del (DEL) | VAF 182/491 reads (37%) | catalogued as rs1305170860; called by pindel, varscan2
- MMP2 | c.1550C>T p.P517L | Missense Mutation (SNP) | VAF 197/413 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs772654963; called by muse, mutect2, varscan2
- MMP24 | c.1517C>T p.T506M | Missense Mutation (SNP) | VAF 101/1081 reads (9%) | SIFT tolerated (0.58); PolyPhen benign (0.019); catalogued as rs765652129, COSV55769918; called by muse, mutect2
- MPP1 | c.616C>T p.R206W | Missense Mutation (SNP) | VAF 248/248 reads (100%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.883); catalogued as rs782521600, COSV65728662; called by muse, mutect2, varscan2
- MS4A15 | c.710A>G p.Q237R (on ENST00000405633 / NM_001098835.2; = p.Q144R on NM_152717.3) | Missense Mutation (SNP) | VAF 48/316 reads (15%) | SIFT tolerated, low confidence (0.14); PolyPhen benign (0.055); catalogued as rs1478145200; called by muse, mutect2, varscan2
- MSH4 | c.2188G>A p.E730K | Missense Mutation (SNP) | VAF 50/98 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as rs866210811, COSV54196342; called by muse, mutect2, varscan2
- MTNR1B | c.125C>T p.A42V | Missense Mutation (SNP) | VAF 360/722 reads (50%) | SIFT tolerated (0.5); PolyPhen benign (0.01); catalogued as COSV57068295; called by muse, mutect2, varscan2
- MUC16 | c.13886C>T p.A4629V | Missense Mutation (SNP) | VAF 195/444 reads (44%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0); catalogued as rs372648706; called by muse, mutect2, varscan2
- MYH7B | c.946C>T p.R316W | Missense Mutation (SNP) | VAF 178/626 reads (28%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs367773248; called by muse, mutect2, varscan2
- MYL6B | c.205T>A p.F69I | Missense Mutation (SNP) | VAF 150/279 reads (54%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.59); catalogued as COSV52879751; called by muse, mutect2, varscan2
- MYO15A | c.1327G>A p.V443I | Missense Mutation (SNP) | VAF 364/669 reads (54%) | SIFT tolerated (0.21); PolyPhen benign (0); catalogued as COSV99233655; called by muse, mutect2, varscan2
- MYOCD | c.2315G>A p.R772Q | Missense Mutation (SNP) | VAF 213/396 reads (54%) | SIFT tolerated (0.35); PolyPhen benign (0.003); catalogued as rs771058548, COSV58497700; called by muse, mutect2, varscan2
- MYT1L | c.1543G>A p.V515I | Missense Mutation (SNP) | VAF 174/388 reads (45%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.991); catalogued as rs765680020, COSV67721562; called by muse, varscan2
- MYT1L | c.1325C>T p.T442M | Missense Mutation (SNP) | VAF 238/496 reads (48%) | SIFT deleterious (0); PolyPhen possibly damaging (0.804); catalogued as rs754747899, COSV67706497; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- NAALADL2 | c.356G>A p.R119H | Missense Mutation (SNP) | VAF 156/306 reads (51%) | SIFT tolerated (0.19); PolyPhen benign (0); catalogued as rs760832134, COSV70795029; called by muse, mutect2, varscan2
- NADK | c.881_883del p.S294del | In Frame Del (DEL) | VAF 204/430 reads (47%) | catalogued as rs1445163006; called by pindel, varscan2
- NASP | c.2309G>A p.R770Q | Missense Mutation (SNP) | VAF 113/239 reads (47%) | SIFT tolerated, low confidence (0.13); PolyPhen benign (0.001); catalogued as rs774108236; called by muse, mutect2, varscan2
- NBEA | c.3974G>A p.R1325Q | Missense Mutation (SNP) | VAF 149/279 reads (53%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.968); catalogued as rs1165053722, COSV59813225; called by muse, mutect2, varscan2
- NBEAL1 | c.3915_3917del p.K1305del | In Frame Del (DEL) | VAF 108/213 reads (51%) | catalogued as rs769531480; called by pindel, varscan2
- NCDN | c.281C>T p.A94V | Missense Mutation (SNP) | VAF 241/496 reads (49%) | SIFT tolerated (0.38); PolyPhen benign (0.013); catalogued as rs753953315, COSV57846751; called by muse, mutect2, varscan2
- NEDD4 | c.257G>A p.R86Q | Missense Mutation (SNP) | VAF 123/296 reads (42%) | SIFT deleterious (0.04); PolyPhen benign (0.061); catalogued as rs774933057, COSV101436641; called by muse, mutect2, varscan2
- NEURL1B | c.842G>A p.R281H | Missense Mutation (SNP) | VAF 259/559 reads (46%) | SIFT tolerated (0.75); PolyPhen benign (0.079); catalogued as rs1460619648; called by muse, mutect2, varscan2
- NID1 | c.1007G>T p.R336L | Missense Mutation (SNP) | VAF 225/457 reads (49%) | SIFT tolerated (0.17); PolyPhen benign (0.007); catalogued as COSV51621005; called by muse, mutect2, varscan2
- NID2 | c.1640T>C p.V547A | Missense Mutation (SNP) | VAF 170/345 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV53495542; called by muse, mutect2, varscan2
- NKX1-1 | c.763G>A p.V255I | Missense Mutation (SNP) | VAF 568/1149 reads (49%) | SIFT tolerated, low confidence (0.3); PolyPhen benign (0.003); catalogued as rs1469500275; called by muse, mutect2
- NOTCH1 | c.4070G>A p.C1357Y | Missense Mutation (SNP) | VAF 35/450 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.724); catalogued as COSV53058547; called by muse, mutect2
- NPC1L1 | c.1273_1274del p.L425Afs*120 | Frame Shift Del (DEL) | VAF 84/512 reads (16%) | catalogued as rs1305301465; called by pindel, varscan2
- NT5DC2 | c.1057G>T p.V353L | Missense Mutation (SNP) | VAF 77/209 reads (37%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.894); catalogued as rs749124845, COSV58732844; called by muse, mutect2, varscan2
- NUFIP1 | c.494dup p.K166Efs*12 | Frame Shift Ins (INS) | VAF 36/218 reads (17%) | catalogued as rs770344882; called by mutect2, varscan2
- OCA2 | c.667G>A p.V223M | Missense Mutation (SNP) | VAF 258/536 reads (48%) | SIFT tolerated (0.23); PolyPhen benign (0.006); catalogued as rs1390458631, COSV62355676; called by muse, mutect2, varscan2
- OCM2 | c.169G>A p.G57R | Missense Mutation (SNP) | VAF 160/362 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs777688959, COSV57535046; called by muse, mutect2, varscan2
- OGDHL | c.2443G>A p.V815M | Missense Mutation (SNP) | VAF 175/355 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.948); catalogued as rs201783448, COSV65103304; called by muse, mutect2, varscan2
- OR2G3 | c.500C>A p.P167H | Missense Mutation (SNP) | VAF 199/418 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100180756; called by muse, mutect2, varscan2
- OR4L1 | c.326del p.G109Vfs*4 | Frame Shift Del (DEL) | VAF 165/351 reads (47%) | catalogued as rs762461085; called by mutect2, pindel, varscan2
- OR4X1 | c.394G>A p.A132T | Missense Mutation (SNP) | VAF 201/411 reads (49%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs1441527199, COSV60722405; called by muse, mutect2, varscan2
- OR51T1 | c.111C>A p.Y37* | Nonsense Mutation (SNP) | VAF 180/374 reads (48%) | catalogued as COSV59026831; called by muse, mutect2, varscan2
- OR52A5 | c.194del p.L65Wfs*20 | Frame Shift Del (DEL) | VAF 159/387 reads (41%) | catalogued as rs762677866, COSV100263457; called by mutect2, pindel, varscan2
- OR52J3 | c.933del p.K311Nfs*? | Frame Shift Del (DEL) | VAF 66/174 reads (38%) | catalogued as rs1254479213; called by mutect2, pindel, varscan2
- OR5AR1 | c.685C>T p.R229C | Missense Mutation (SNP) | VAF 160/315 reads (51%) | SIFT tolerated (0.05); PolyPhen benign (0.001); catalogued as rs758374441, COSV57254483; called by muse, mutect2, varscan2
- OR5M10 | c.638T>C p.I213T | Missense Mutation (SNP) | VAF 203/387 reads (52%) | SIFT tolerated (0.07); PolyPhen benign (0.367); catalogued as COSV73242350; called by muse, mutect2, varscan2
- OR7C2 | c.535dup p.C179Lfs*2 | Frame Shift Ins (INS) | VAF 122/254 reads (48%) | catalogued as rs747041500; called by mutect2, varscan2
- OR8J2 | c.29C>T p.T10M | Missense Mutation (SNP) | VAF 86/225 reads (38%) | SIFT deleterious (0.02); PolyPhen benign (0.111); catalogued as rs749563072; called by muse, mutect2
- OSBPL9 | c.2110_2112del p.E704del | In Frame Del (DEL) | VAF 131/280 reads (47%) | catalogued as rs1163251306; called by mutect2, pindel, varscan2
- OTOG | c.8690G>A p.R2897H | Missense Mutation (SNP) | VAF 306/632 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as rs767373345; called by muse, mutect2
- P3H1 | c.932A>G p.Y311C | Missense Mutation (SNP) | VAF 111/229 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs368079962; called by muse, mutect2, varscan2
- PAPLN | c.2918C>T p.A973V (on ENST00000554301; = p.A946V on NM_173462.4) | Missense Mutation (SNP) | VAF 215/427 reads (50%) | SIFT deleterious (0); PolyPhen possibly damaging (0.906); catalogued as rs370180276, COSV53718165; called by muse, mutect2, varscan2
- PAX1 | c.1400G>T p.R467L | Missense Mutation (SNP) | VAF 302/302 reads (100%) | SIFT tolerated, low confidence (0.28); PolyPhen benign (0.003); catalogued as rs752368901, COSV104433357; called by muse, mutect2, varscan2
- PCDHB16 | c.2203C>T p.R735C | Missense Mutation (SNP) | VAF 260/546 reads (48%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.255); catalogued as rs1311553957, COSV53357820; called by muse, mutect2
- PCLO | c.11396G>A p.R3799Q | Missense Mutation (SNP) | VAF 194/423 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs919590129, COSV61615295; called by muse, mutect2, varscan2
- PDCD1 | c.105dup p.T36Hfs*70 | Frame Shift Ins (INS) | VAF 236/526 reads (45%) | catalogued as rs768249210; called by mutect2, varscan2
- PDE10A | c.1670T>C p.L557P | Missense Mutation (SNP) | VAF 121/121 reads (100%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV63101112; called by muse, mutect2, varscan2
- PDIA4 | c.1202G>A p.R401H (on ENST00000286091 / NM_001371244.1; = p.R400H on NM_004911.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 209/439 reads (48%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.992); catalogued as rs780487329; called by muse, varscan2
- PDZD2 | c.7694A>G p.Q2565R | Missense Mutation (SNP) | VAF 154/315 reads (49%) | SIFT tolerated (0.38); PolyPhen benign (0.001); catalogued as rs772823366; called by muse, mutect2, varscan2
- PEDS1 | c.226G>A p.V76I | Missense Mutation (SNP) | VAF 150/482 reads (31%) | SIFT tolerated (0.86); PolyPhen benign (0); catalogued as rs148820409; called by muse, varscan2
- PFAS | c.3963del p.W1322Gfs*32 | Frame Shift Del (DEL) | VAF 248/479 reads (52%) | catalogued as COSV58980444; called by mutect2, varscan2
- PHF3 | c.2910dup p.R971Sfs*6 | Frame Shift Ins (INS) | VAF 29/103 reads (28%) | catalogued as rs755026826; called by mutect2, varscan2
- PIEZO2 | c.1377A>G p.S459= | Splice Region (SNP) | VAF 233/391 reads (60%) | catalogued as rs1451736408; called by muse, mutect2, varscan2
- PIKFYVE | c.304C>T p.R102W | Missense Mutation (SNP) | VAF 152/291 reads (52%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.993); catalogued as rs752312510, COSV52238249; called by muse, mutect2, varscan2
- PKD1 | c.12817C>T p.R4273C (on ENST00000262304 / NM_001009944.3; = p.R4272C on NM_000296.4) | Missense Mutation (SNP) | VAF 456/942 reads (48%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.623); catalogued as rs144648696; called by muse, mutect2
- PKD1L1 | c.5380G>T p.G1794C | Missense Mutation (SNP) | VAF 196/417 reads (47%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.862); catalogued as rs767372078; called by muse, mutect2, varscan2
- PKDREJ | c.4074C>A p.F1358L | Missense Mutation (SNP) | VAF 162/352 reads (46%) | SIFT tolerated (0.06); PolyPhen benign (0.164); catalogued as COSV53548540, COSV99479673; called by muse, mutect2, varscan2
- PKM | c.946C>T p.R316W | Missense Mutation (SNP) | VAF 41/460 reads (9%) | SIFT deleterious (0.04); PolyPhen benign (0.298); catalogued as rs147956260, COSV58787190; called by muse, mutect2
- PLA2G4E | c.1919A>G p.N640S | Missense Mutation (SNP) | VAF 245/535 reads (46%) | SIFT tolerated (0.54); PolyPhen benign (0.007); catalogued as rs377526076; called by muse, mutect2, varscan2
- PLA2G4F | c.623C>T p.A208V | Missense Mutation (SNP) | VAF 206/422 reads (49%) | SIFT deleterious (0.02); PolyPhen benign (0.003); catalogued as rs1419421392; called by muse, mutect2
- PLCB4 | c.1357G>A p.D453N | Missense Mutation (SNP) | VAF 17/138 reads (12%) | SIFT tolerated (0.49); PolyPhen probably damaging (0.992); catalogued as rs867755017; called by muse, mutect2, varscan2
- PLEKHH1 | c.1116G>T p.E372D | Missense Mutation (SNP) | VAF 67/448 reads (15%) | SIFT tolerated (0.55); PolyPhen benign (0); catalogued as COSV100233003; called by muse, mutect2, varscan2
- PLK5 | c.673C>T p.R225C | Missense Mutation (SNP) | VAF 262/591 reads (44%) | SIFT deleterious (0.01); PolyPhen benign (0); catalogued as rs1353185384, COSV58292552; called by muse, mutect2, varscan2
- PLOD1 | c.1763G>A p.R588H | Missense Mutation (SNP) | VAF 165/343 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs755346019, COSV52143608; called by muse, mutect2, varscan2
- PLXND1 | c.2084C>T p.A695V | Missense Mutation (SNP) | VAF 334/676 reads (49%) | SIFT tolerated (0.05); PolyPhen benign (0.079); catalogued as rs937819113; called by muse, mutect2, varscan2
- PMIS2 | c.62C>T p.A21V | Missense Mutation (SNP) | VAF 281/640 reads (44%) | SIFT tolerated, low confidence (0.1); catalogued as rs141347027; called by muse, mutect2
- PNPLA6 | c.2995G>A p.A999T (on ENST00000414982 / NM_001166111.2; = p.A951T on NM_006702.5) | Missense Mutation (SNP) | VAF 177/380 reads (47%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.995); catalogued as rs1369120103; called by muse, mutect2, varscan2
- PNPLA8 | c.339G>T p.K113N | Missense Mutation (SNP) | VAF 23/306 reads (8%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.998); catalogued as rs1345488563, COSV57554999; called by muse, mutect2
- POLK | c.1588A>G p.I530V | Missense Mutation (SNP) | VAF 131/265 reads (49%) | SIFT tolerated (0.48); PolyPhen benign (0.001); catalogued as rs867423497; called by muse, mutect2, varscan2
- POLR1E | c.340C>A p.P114T (on ENST00000377792 / NM_001282766.1; = p.P52T on NM_022490.4) | Missense Mutation (SNP) | VAF 150/152 reads (99%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.99); catalogued as COSV100905429; called by muse, mutect2, varscan2
- PPARGC1B | c.2233G>A p.A745T | Missense Mutation (SNP) | VAF 60/512 reads (12%) | SIFT tolerated (0.31); PolyPhen benign (0.039); catalogued as rs1436290627; called by muse, varscan2
- PPFIA2 | c.2269G>A p.V757I | Missense Mutation (SNP) | VAF 90/181 reads (50%) | SIFT tolerated (0.17); PolyPhen benign (0.052); catalogued as rs376334232; called by muse, mutect2, varscan2
- PPHLN1 | c.1222A>G p.I408V | Missense Mutation (SNP) | VAF 212/424 reads (50%) | SIFT tolerated, low confidence (0.16); PolyPhen benign (0.031); catalogued as rs774306697; called by muse, mutect2, varscan2
- PPIP5K2 | c.2827C>T p.R943* | Nonsense Mutation (SNP) | VAF 97/252 reads (38%) | catalogued as rs550590492, COSV58603146; called by muse, mutect2, varscan2
- PPM1B | c.238A>G p.T80A | Missense Mutation (SNP) | VAF 159/346 reads (46%) | SIFT tolerated (0.17); PolyPhen benign (0.022); catalogued as rs1442639738; called by muse, mutect2, varscan2
- PPTC7 | c.299C>T p.T100M | Missense Mutation (SNP) | VAF 47/376 reads (13%) | SIFT deleterious (0.04); PolyPhen benign (0.233); catalogued as rs1277287052; called by muse, mutect2, varscan2
- PRAG1 | c.3943C>T p.R1315C | Missense Mutation (SNP) | VAF 186/610 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1448304987, COSV58160454; called by muse, varscan2
- PRDM10 | c.1903G>A p.V635M | Missense Mutation (SNP) | VAF 36/234 reads (15%) | SIFT tolerated (0.31); PolyPhen possibly damaging (0.719); catalogued as rs370512969; called by muse, mutect2, varscan2
- PRDM16 | c.3791C>T p.T1264M | Missense Mutation (SNP) | VAF 44/598 reads (7%) | SIFT deleterious (0.03); PolyPhen benign (0.266); catalogued as rs778185431; called by muse, mutect2
- PRR14 | c.1607G>A p.R536H | Missense Mutation (SNP) | VAF 301/597 reads (50%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as rs903673551, COSV54910941; called by muse, varscan2
- PTN | c.123dup p.V42Sfs*5 | Frame Shift Ins (INS) | VAF 94/208 reads (45%) | catalogued as rs777801558; called by mutect2, varscan2
- PTPN23 | c.4796G>A p.R1599Q | Missense Mutation (SNP) | VAF 350/352 reads (99%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.67); catalogued as rs148181021; called by muse, mutect2, varscan2
- PTPRB | c.3543del p.S1182Pfs*25 | Frame Shift Del (DEL) | VAF 114/309 reads (37%) | catalogued as COSV99716601; called by mutect2, pindel, varscan2
- PXDN | c.1433G>A p.R478Q | Missense Mutation (SNP) | VAF 144/287 reads (50%) | SIFT tolerated (0.2); PolyPhen benign (0.392); catalogued as rs777271860; called by muse, mutect2, varscan2
- RAD54L2 | c.3788C>T p.A1263V | Missense Mutation (SNP) | VAF 20/357 reads (6%) | SIFT tolerated, low confidence (0.34); PolyPhen benign (0); catalogued as rs1234546301; called by muse, mutect2
- RALBP1 | c.415_417del p.E139del | In Frame Del (DEL) | VAF 118/222 reads (53%) | catalogued as rs1298277625; called by pindel, varscan2
- RASSF5 | c.986A>G p.Q329R | Missense Mutation (SNP) | VAF 264/540 reads (49%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.995); catalogued as rs1558524714; called by muse, mutect2, varscan2
- RBL1 | c.566G>A p.R189Q | Missense Mutation (SNP) | VAF 114/319 reads (36%) | SIFT tolerated (0.22); PolyPhen possibly damaging (0.464); catalogued as rs368117514; called by muse, varscan2
- RBMXL2 | c.325C>T p.R109C | Missense Mutation (SNP) | VAF 252/487 reads (52%) | SIFT deleterious (0); PolyPhen possibly damaging (0.683); catalogued as rs1261223303; called by muse, mutect2, varscan2
- RGPD4 | c.4654A>G p.S1552G | Missense Mutation (SNP) | VAF 31/385 reads (8%) | SIFT deleterious (0.01); PolyPhen benign (0.132); catalogued as rs1323531237; called by muse, mutect2, varscan2
- RIF1 | c.4322del p.K1441Rfs*18 | Frame Shift Del (DEL) | VAF 129/344 reads (38%) | catalogued as rs767284433; called by mutect2, pindel, varscan2
- RNF175 | c.373C>T p.R125* | Nonsense Mutation (SNP) | VAF 130/260 reads (50%) | catalogued as rs766172106, COSV99923862; called by muse, mutect2, varscan2
- RNF213 | c.12841C>T p.R4281W | Missense Mutation (SNP) | VAF 238/455 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs765980348, COSV60400499, COSV60406277; ClinVar: other; called by muse, varscan2
- RNF220 | c.1396A>C p.S466R | Missense Mutation (SNP) | VAF 263/525 reads (50%) | SIFT deleterious (0.04); PolyPhen benign (0.137); catalogued as rs1490747042; called by muse, mutect2, varscan2
- ROBO1 | c.4183G>T p.G1395C | Missense Mutation (SNP) | VAF 165/165 reads (100%) | SIFT deleterious (0); PolyPhen possibly damaging (0.846); catalogued as COSV71392550; called by muse, mutect2, varscan2
- ROR2 | c.211A>G p.I71V | Missense Mutation (SNP) | VAF 120/121 reads (99%) | SIFT tolerated (0.17); PolyPhen probably damaging (0.987); catalogued as rs745733784; called by muse, mutect2, varscan2
- RPL22 | c.44del p.K15Rfs*5 | Frame Shift Del (DEL) | VAF 182/375 reads (49%) | catalogued as rs759765382, COSV52379423; called by mutect2, varscan2
- RXFP2 | c.428C>G p.S143C | Missense Mutation (SNP) | VAF 74/172 reads (43%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.886); catalogued as COSV53634048; called by muse, mutect2, varscan2
- RYR1 | c.4306G>A p.V1436M | Missense Mutation (SNP) | VAF 138/293 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs200289457, COSV100614600; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- RYR1 | c.7697C>T p.A2566V | Missense Mutation (SNP) | VAF 348/715 reads (49%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.98); catalogued as rs1285547623, COSV62089550; called by muse, mutect2, varscan2
- RYR3 | c.7109G>A p.R2370H (on ENST00000389232; = p.R2371H on NM_001036.6) | Missense Mutation (SNP) | VAF 192/385 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1234585541, COSV101212486; called by muse, varscan2
- S1PR2 | c.1025C>T p.T342M | Missense Mutation (SNP) | VAF 249/546 reads (46%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.745); catalogued as rs762697846; called by muse, mutect2, varscan2
- SAMD11 | c.199C>T p.R67W | Missense Mutation (SNP) | VAF 64/549 reads (12%) | SIFT tolerated (0.06); PolyPhen benign (0.001); catalogued as COSV100574702; called by muse, mutect2, varscan2
- SBNO1 | c.2376_2378del p.K793del (on ENST00000420886; = p.K792del on NM_018183.5) | In Frame Del (DEL) | VAF 98/236 reads (42%) | catalogued as rs770322303; called by pindel, varscan2
- SBSPON | c.587G>A p.R196Q | Missense Mutation (SNP) | VAF 220/464 reads (47%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.933); catalogued as rs202151174; called by muse, mutect2
- SCAP | c.550C>T p.R184C | Missense Mutation (SNP) | VAF 208/208 reads (100%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.608); catalogued as rs879008440; called by muse, mutect2, varscan2
- SCART1 | c.1078G>A p.A360T | Missense Mutation (SNP) | VAF 244/514 reads (47%) | SIFT deleterious (0.03); PolyPhen benign (0.41); catalogued as rs928295221; called by muse, mutect2, varscan2
- SCFD2 | c.1759G>A p.E587K | Missense Mutation (SNP) | VAF 204/429 reads (48%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.734); catalogued as rs756696217, COSV101189308, COSV101189422; called by muse, mutect2, varscan2
- SCYL3 | c.1093G>A p.V365M | Missense Mutation (SNP) | VAF 30/474 reads (6%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.855); catalogued as rs752839423, COSV100884292; called by muse, mutect2
- SDK2 | c.2867C>T p.T956M | Missense Mutation (SNP) | VAF 246/529 reads (47%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.895); catalogued as rs1320889649, COSV66186848; called by muse, mutect2, varscan2
- SEC23IP | c.2840G>A p.R947Q | Missense Mutation (SNP) | VAF 56/372 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs200302175, COSV64831493; called by muse, mutect2, varscan2
- SECISBP2 | c.2161C>T p.Q721* | Nonsense Mutation (SNP) | VAF 32/214 reads (15%) | catalogued as rs770702684; called by muse, mutect2, varscan2
- SENP3 | c.776G>A p.R259H | Missense Mutation (SNP) | VAF 50/439 reads (11%) | SIFT deleterious (0.03); PolyPhen benign (0); catalogued as rs781493025, COSV99548052; called by muse, mutect2, varscan2
- SETD1A | c.4651G>A p.A1551T | Missense Mutation (SNP) | VAF 163/354 reads (46%) | SIFT tolerated (0.24); PolyPhen probably damaging (0.99); catalogued as rs771053823, COSV52680345; called by muse, mutect2, varscan2
- SEZ6L | c.2062G>A p.E688K | Missense Mutation (SNP) | VAF 196/364 reads (54%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.823); catalogued as rs1211422692, COSV50660109, COSV99962860; called by muse, mutect2, varscan2
- SH2B2 | c.1434del p.R480Gfs*7 | Frame Shift Del (DEL) | VAF 268/658 reads (41%) | catalogued as COSV60827874; called by mutect2, pindel, varscan2
- SH2D3A | c.1364G>A p.R455Q | Missense Mutation (SNP) | VAF 268/535 reads (50%) | SIFT deleterious (0.05); PolyPhen benign (0.186); catalogued as rs1203616918; called by muse, mutect2, varscan2
- SH3BP4 | c.2168G>A p.G723D | Missense Mutation (SNP) | VAF 332/652 reads (51%) | SIFT tolerated (0.2); PolyPhen probably damaging (0.999); catalogued as rs1246711878; called by muse, mutect2, varscan2
- SH3PXD2A | c.2815G>A p.V939I (on ENST00000369774 / NM_001365079.1; = p.V911I on NM_014631.2) | Missense Mutation (SNP) | VAF 296/633 reads (47%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs773259897, COSV60115705; called by muse, mutect2, varscan2
- SH3RF3 | c.1513del p.A505Rfs*3 | Frame Shift Del (DEL) | VAF 214/535 reads (40%) | catalogued as COSV58685960, COSV58695199; called by mutect2, pindel, varscan2
- SHANK1 | c.2353C>T p.R785C | Missense Mutation (SNP) | VAF 54/393 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs946919605; called by muse, mutect2, varscan2
- SHROOM2 | c.282G>T p.K94N | Missense Mutation (SNP) | VAF 241/524 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV66604853; called by muse, mutect2, varscan2
- SI | c.4043C>T p.T1348M | Missense Mutation (SNP) | VAF 85/193 reads (44%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.959); catalogued as rs192640245; called by muse, mutect2, varscan2
- SIM1 | c.664G>A p.V222I | Missense Mutation (SNP) | VAF 224/224 reads (100%) | SIFT tolerated (1); PolyPhen benign (0.037); catalogued as rs374696271, COSV53492540; called by muse, mutect2, varscan2
- SIN3A | c.56G>A p.R19Q | Missense Mutation (SNP) | VAF 21/522 reads (4%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0.003); catalogued as rs1210128185, COSV64583937; called by muse, mutect2
- SIPA1L2 | c.736G>A p.A246T | Missense Mutation (SNP) | VAF 130/278 reads (47%) | SIFT tolerated (0.42); PolyPhen benign (0.041); catalogued as rs1167028057; called by muse, mutect2, varscan2
- SLC12A3 | c.2782G>A p.A928T (on ENST00000563236 / NM_001126108.2; = p.A937T on NM_000339.3) | Missense Mutation (SNP) | VAF 178/363 reads (49%) | SIFT tolerated (0.51); PolyPhen benign (0.027); catalogued as rs1268374499; called by muse, mutect2, varscan2
- SLC12A6 | c.2024G>A p.R675Q (on ENST00000354181 / NM_001365088.1; = p.R624Q on NM_005135.2) | Missense Mutation (SNP) | VAF 132/296 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV99271565; called by muse, mutect2, varscan2
- SLC22A5 | c.1651A>G p.I551V | Missense Mutation (SNP) | VAF 54/373 reads (14%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as rs745329092; called by muse, mutect2, varscan2
- SLC29A4 | c.986G>A p.R329Q | Missense Mutation (SNP) | VAF 302/638 reads (47%) | SIFT tolerated (0.64); PolyPhen benign (0.012); catalogued as rs774145930; called by muse, mutect2
- SLC44A3 | c.1722del p.F574Lfs*4 (on ENST00000271227 / NM_001114106.3; = p.F526Lfs*4 on NM_152369.5 and 1 other RefSeq transcript) | Frame Shift Del (DEL) | VAF 180/497 reads (36%) | catalogued as rs752543591, COSV54732637; called by mutect2, pindel, varscan2
- SLC48A1 | c.379A>G p.S127G | Missense Mutation (SNP) | VAF 38/640 reads (6%) | SIFT tolerated (0.58); PolyPhen benign (0); catalogued as rs1365677655; called by muse, mutect2
- SLITRK4 | c.734C>A p.P245H | Missense Mutation (SNP) | VAF 218/458 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV62022634; called by mutect2, varscan2
- SNTB2 | c.862G>A p.A288T | Missense Mutation (SNP) | VAF 110/402 reads (27%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.989); catalogued as rs1378906819; called by muse, varscan2
- SNX18 | c.1245del p.A416Pfs*42 | Frame Shift Del (DEL) | VAF 302/661 reads (46%) | catalogued as rs779304883; called by mutect2, pindel, varscan2
- SNX18 | c.1759G>A p.V587I | Missense Mutation (SNP) | VAF 178/408 reads (44%) | PolyPhen benign (0.005); catalogued as COSV57991357; called by muse, mutect2, varscan2
- SNX7 | c.80del p.G27Afs*38 | Frame Shift Del (DEL) | VAF 323/812 reads (40%) | catalogued as rs1296656242; called by mutect2, pindel, varscan2
- SOX5 | c.1307C>T p.A436V | Missense Mutation (SNP) | VAF 142/292 reads (49%) | SIFT tolerated (0.29); PolyPhen benign (0.015); catalogued as rs745428574, COSV58621446; called by muse, mutect2, varscan2
- SPAG5 | c.1060G>A p.V354I | Missense Mutation (SNP) | VAF 214/429 reads (50%) | SIFT tolerated (0.14); PolyPhen benign (0.015); catalogued as rs747402791; called by muse, mutect2, varscan2
- SPATA16 | c.337C>T p.P113S | Missense Mutation (SNP) | VAF 147/326 reads (45%) | SIFT tolerated (0.53); PolyPhen possibly damaging (0.509); catalogued as rs778611950, COSV100650911; called by muse, mutect2, varscan2
- SPATS2L | c.1127C>T p.A376V | Missense Mutation (SNP) | VAF 197/398 reads (49%) | SIFT tolerated (0.09); PolyPhen benign (0.001); catalogued as rs751577050, COSV62352821; called by muse, mutect2, varscan2
- SPDL1 | c.68C>T p.A23V | Missense Mutation (SNP) | VAF 25/391 reads (6%) | SIFT deleterious (0); PolyPhen possibly damaging (0.808); catalogued as rs1407439521; called by muse, mutect2
- SPHKAP | c.1775C>T p.A592V | Missense Mutation (SNP) | VAF 182/398 reads (46%) | SIFT tolerated (0.12); PolyPhen benign (0.015); catalogued as COSV60869857; called by muse, mutect2, varscan2
- SREBF1 | c.2464C>A p.P822T | Missense Mutation (SNP) | VAF 149/314 reads (47%) | SIFT tolerated (0.21); PolyPhen benign (0.304); catalogued as rs753379159; called by muse, mutect2, varscan2
- SSX3 | c.481del p.E161Nfs*15 | Frame Shift Del (DEL) | VAF 156/472 reads (33%) | catalogued as COSV53646006; called by pindel, varscan2
- STAB2 | c.2278G>A p.G760S | Missense Mutation (SNP) | VAF 151/332 reads (45%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs761459390, COSV101185700; called by muse, mutect2, varscan2
- STAB2 | c.6781G>A p.A2261T | Missense Mutation (SNP) | VAF 192/429 reads (45%) | SIFT tolerated (0.13); PolyPhen benign (0.007); catalogued as rs147296184; called by muse, mutect2, varscan2
- STAG2 | c.1400del p.F467Sfs*3 | Frame Shift Del (DEL) | VAF 38/291 reads (13%) | catalogued as COSV54376603; called by mutect2, pindel, varscan2
- STK32B | c.869C>T p.A290V | Missense Mutation (SNP) | VAF 211/422 reads (50%) | SIFT tolerated (0.14); PolyPhen benign (0.013); catalogued as rs150966427; called by muse, mutect2, varscan2
- SULF2 | c.670G>A p.A224T | Missense Mutation (SNP) | VAF 275/816 reads (34%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.99); catalogued as rs1156246531; called by muse, mutect2, varscan2
- SUN1 | c.1322C>T p.A441V (on ENST00000405266 / NM_001367651.1; = p.A321V on NM_025154.6 and 13 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 32/498 reads (6%) | SIFT tolerated (0.29); PolyPhen benign (0.093); catalogued as rs779899978; called by muse, mutect2
- SUSD2 | c.719G>A p.S240N | Missense Mutation (SNP) | VAF 159/552 reads (29%) | SIFT tolerated (0.69); PolyPhen benign (0); catalogued as rs1201311712; called by muse, mutect2, varscan2
- SYNE1 | c.10212G>T p.W3404C (on ENST00000367255 / NM_182961.4; = p.W3411C on NM_033071.3) | Missense Mutation (SNP) | VAF 15/199 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs1179568983; called by muse, mutect2
- SYT3 | c.1276G>A p.G426S | Missense Mutation (SNP) | VAF 187/418 reads (45%) | SIFT tolerated (0.19); PolyPhen benign (0.001); catalogued as rs745650170; called by muse, mutect2, varscan2
- SYTL5 | c.1842-1G>A p.X614_splice | Splice Site (SNP) | VAF 116/253 reads (46%) | catalogued as COSV52899696; called by muse, mutect2, varscan2
- TACC2 | c.3880dup p.L1294Pfs*20 | Frame Shift Ins (INS) | VAF 59/524 reads (11%) | catalogued as rs1565262628; called by mutect2, varscan2
- TADA3 | c.430C>T p.R144W | Missense Mutation (SNP) | VAF 140/140 reads (100%) | SIFT deleterious (0); PolyPhen probably damaging (0.928); catalogued as rs1559721021; called by muse, mutect2, varscan2
- TAF4 | c.2282C>T p.T761M | Missense Mutation (SNP) | VAF 312/985 reads (32%) | SIFT deleterious (0); PolyPhen possibly damaging (0.899); catalogued as rs777163384; called by muse, mutect2, varscan2
- TARBP2 | c.838C>T p.R280C (on ENST00000266987 / NM_134323.2; = p.R259C on NM_004178.4) | Missense Mutation (SNP) | VAF 68/685 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.719); catalogued as rs766949070; called by muse, mutect2
- TBC1D16 | c.826G>A p.G276S | Missense Mutation (SNP) | VAF 254/504 reads (50%) | SIFT tolerated (0.4); PolyPhen benign (0.122); catalogued as rs780785193; called by muse, varscan2
- TCF3 | c.1081del p.Q361Rfs*33 | Frame Shift Del (DEL) | VAF 187/405 reads (46%) | catalogued as rs1329397192; called by mutect2, pindel, varscan2
- TCHH | c.3113G>A p.R1038Q | Missense Mutation (SNP) | VAF 296/812 reads (36%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.022); catalogued as rs1398106917; called by muse, varscan2
- TCIRG1 | c.2376_2379del p.E792Dfs*28 | Frame Shift Del (DEL) | VAF 210/502 reads (42%) | catalogued as rs1189520104; called by mutect2, pindel, varscan2
- TDRD5 | c.1005del p.K335Nfs*2 | Frame Shift Del (DEL) | VAF 84/186 reads (45%) | catalogued as rs772423686; called by mutect2, pindel, varscan2
- THBS1 | c.2428C>T p.R810W | Missense Mutation (SNP) | VAF 103/252 reads (41%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.913); catalogued as rs760644149, COSV52952137; called by muse, mutect2, varscan2
- TIPARP | c.639C>A p.D213E | Missense Mutation (SNP) | VAF 104/224 reads (46%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.257); catalogued as COSV99904042; called by muse, mutect2, varscan2
- TLE1 | c.1178G>C p.S393T | Missense Mutation (SNP) | VAF 42/343 reads (12%) | SIFT deleterious (0.03); PolyPhen benign (0.12); catalogued as COSV64691355; called by muse, mutect2, varscan2
- TMEM185A | c.521C>T p.P174L | Missense Mutation (SNP) | VAF 9/42 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs201614120; called by mutect2, varscan2
- TNFAIP8L1 | c.281C>T p.A94V | Missense Mutation (SNP) | VAF 299/589 reads (51%) | SIFT tolerated (0.4); PolyPhen benign (0.005); catalogued as rs1446562090, COSV59420863; called by muse, mutect2, varscan2
- TNKS | c.1058C>T p.A353V | Missense Mutation (SNP) | VAF 114/222 reads (51%) | SIFT tolerated (0.24); PolyPhen benign (0.044); catalogued as rs1462401273; called by muse, mutect2, varscan2
- TNKS2 | c.1535_1536del p.C512Yfs*11 | Frame Shift Del (DEL) | VAF 111/231 reads (48%) | catalogued as rs752957474; called by pindel, varscan2
- TNNI3K | c.1870C>T p.Q624* | Nonsense Mutation (SNP) | VAF 104/234 reads (44%) | catalogued as rs200226149, COSV58562346; called by muse, mutect2, varscan2
- TP53 | c.365_366del p.V122Dfs*26 | Frame Shift Del (DEL) | VAF 126/334 reads (38%) | catalogued as rs587780067; called by pindel, varscan2
- TP53BP2 | c.2033G>A p.G678D (on ENST00000343537 / NM_001031685.3; = p.G549D on NM_005426.2) | Missense Mutation (SNP) | VAF 199/378 reads (53%) | SIFT tolerated (0.23); PolyPhen benign (0.006); catalogued as COSV59066067, COSV59067622; called by muse, mutect2, varscan2
- TRIM64B | c.1012G>T p.G338C | Missense Mutation (SNP) | VAF 170/736 reads (23%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.644); catalogued as COSV61693652; called by muse, varscan2
- TRIM65 | c.915del p.V306Wfs*17 | Frame Shift Del (DEL) | VAF 67/393 reads (17%) | catalogued as rs140475639; called by mutect2, pindel, varscan2
- TRO | c.2417G>A p.S806N | Missense Mutation (SNP) | VAF 38/724 reads (5%) | SIFT tolerated, low confidence (0.27); PolyPhen benign (0.026); catalogued as COSV51508463; called by muse, mutect2
- TSC2 | c.3989C>T p.T1330M | Missense Mutation (SNP) | VAF 233/490 reads (48%) | SIFT tolerated, low confidence (0.15); PolyPhen benign (0.127); catalogued as rs397515209, CM122780, COSV51920027; ClinVar: uncertain significance / not provided / benign / conflicting interpretations of pathogenicity; called by muse, mutect2, varscan2
- TSPAN4 | c.296C>T p.T99I | Missense Mutation (SNP) | VAF 200/477 reads (42%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as rs754685019; called by muse, varscan2
- TUBB6 | c.811G>A p.A271T | Missense Mutation (SNP) | VAF 56/832 reads (7%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.619); catalogued as rs759418281, COSV52314427; called by muse, mutect2
- TYK2 | c.692G>T p.R231L | Missense Mutation (SNP) | VAF 52/664 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.587); catalogued as COSV53392286, COSV99314631; called by muse, mutect2
- U2AF1L4 | c.467G>A p.R156H (on ENST00000412391; = p.R117H on NM_001040425.3) | Missense Mutation (SNP) | VAF 280/505 reads (55%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.565); catalogued as rs746648207, COSV53075817, COSV53076330; called by muse, mutect2, varscan2
- UBAP2L | c.427G>T p.G143C | Missense Mutation (SNP) | VAF 70/367 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1276784910; called by muse, mutect2, varscan2
- UBE3B | c.1427A>G p.Q476R | Missense Mutation (SNP) | VAF 160/349 reads (46%) | SIFT deleterious (0); PolyPhen possibly damaging (0.757); catalogued as rs1566090452; called by muse, mutect2, varscan2
- UBE4B | c.1329del p.A444Hfs*14 (on ENST00000343090 / NM_001105562.3; = p.A315Hfs*14 on NM_006048.5) | Frame Shift Del (DEL) | VAF 100/224 reads (45%) | catalogued as rs758215455, COSV53529804; called by mutect2, varscan2
- UNC13C | c.1831C>G p.Q611E | Missense Mutation (SNP) | VAF 145/309 reads (47%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); catalogued as COSV99523876; called by muse, mutect2, varscan2
- UNC79 | c.2207G>A p.R736Q (on ENST00000393151 / NM_001346218.2; = p.R559Q on NM_020818.5) | Missense Mutation (SNP) | VAF 14/316 reads (4%) | SIFT tolerated (0.23); PolyPhen benign (0.118); catalogued as rs775625813, COSV99829710; called by muse, mutect2
- UNKL | c.442C>T p.R148W | Missense Mutation (SNP) | VAF 216/428 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1177262207; called by muse, mutect2, varscan2
- UQCRB | c.155C>A p.P52H | Missense Mutation (SNP) | VAF 162/328 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs1259052571; called by mutect2, varscan2
- URB2 | c.3716C>T p.T1239M | Missense Mutation (SNP) | VAF 197/420 reads (47%) | SIFT deleterious (0); PolyPhen possibly damaging (0.886); catalogued as rs199788278; called by muse, varscan2
- USP1 | c.1351_1355del p.E451Ffs*12 | Frame Shift Del (DEL) | VAF 118/281 reads (42%) | catalogued as rs1205944651; called by pindel, varscan2
- USP12 | c.854G>A p.R285H | Missense Mutation (SNP) | VAF 171/334 reads (51%) | SIFT deleterious (0.01); PolyPhen benign (0.125); catalogued as rs776417947, COSV56655413; called by muse, mutect2, varscan2
- UTP25 | c.832del p.L278Sfs*7 | Frame Shift Del (DEL) | VAF 210/412 reads (51%) | catalogued as rs750214623; called by mutect2, varscan2
- VPS13B | c.11014G>A p.A3672T | Missense Mutation (SNP) | VAF 173/388 reads (45%) | SIFT deleterious (0.02); PolyPhen benign (0.078); catalogued as rs868118584, COSV100662212; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- VPS13D | c.9603G>A p.M3201I | Missense Mutation (SNP) | VAF 14/422 reads (3%) | SIFT tolerated (0.13); PolyPhen benign (0.003); catalogued as COSV50625189; called by muse, mutect2
- VPS37C | c.28C>T p.Q10* | Nonsense Mutation (SNP) | VAF 151/357 reads (42%) | catalogued as COSV57109253; called by muse, mutect2, varscan2
- VRTN | c.400C>T p.R134C | Missense Mutation (SNP) | VAF 316/612 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (0.953); catalogued as rs1330449009, COSV56440995, COSV56441603; called by muse, varscan2
- WASF3 | c.1439G>A p.R480Q | Missense Mutation (SNP) | VAF 189/410 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as rs774882598; called by muse, mutect2, varscan2
- WDFY3 | c.6119T>C p.V2040A | Missense Mutation (SNP) | VAF 156/324 reads (48%) | SIFT tolerated (0.51); PolyPhen benign (0.001); catalogued as rs770417953; called by muse, mutect2, varscan2
- WDR45 | c.331C>T p.R111C (on ENST00000376372 / NM_001029896.2; = p.R112C on NM_007075.3) | Missense Mutation (SNP) | VAF 220/490 reads (45%) | SIFT deleterious (0.01); PolyPhen benign (0.068); catalogued as rs781985024, COSV59875519; called by muse, mutect2, varscan2
- WNK3 | c.3877C>T p.R1293C | Missense Mutation (SNP) | VAF 119/249 reads (48%) | SIFT tolerated (0.05); PolyPhen benign (0); catalogued as rs1230331380, COSV63615299; called by muse, mutect2, varscan2
- ZBTB9 | c.1070del p.G357Vfs*15 | Frame Shift Del (DEL) | VAF 66/361 reads (18%) | catalogued as COSV67702478; called by mutect2, pindel, varscan2
- ZC3H12D | c.1264C>A p.L422M | Missense Mutation (SNP) | VAF 449/450 reads (100%) | SIFT tolerated (0.32); PolyPhen benign (0.006); catalogued as rs781439381, COSV66324288; called by muse, mutect2, varscan2
- ZC3H13 | c.2308C>T p.R770* | Nonsense Mutation (SNP) | VAF 236/555 reads (43%) | catalogued as COSV104387502; called by muse, mutect2, varscan2
- ZDHHC7 | c.831del p.S280Hfs*5 | Frame Shift Del (DEL) | VAF 244/501 reads (49%) | catalogued as COSV58214455; called by mutect2, varscan2
- ZEB1 | c.3020C>T p.S1007L | Missense Mutation (SNP) | VAF 189/376 reads (50%) | SIFT tolerated (0.28); PolyPhen benign (0.003); catalogued as rs1041866704; called by muse, mutect2, varscan2
- ZFHX3 | c.8606C>T p.S2869F | Missense Mutation (SNP) | VAF 16/506 reads (3%) | SIFT tolerated (0.71); PolyPhen benign (0.125); catalogued as rs1176929730; called by muse, mutect2
- ZNF169 | c.332C>T p.A111V | Missense Mutation (SNP) | VAF 185/185 reads (100%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs762656741, COSV61764168; called by muse, mutect2, varscan2
- ZNF23 | c.596C>T p.S199L | Missense Mutation (SNP) | VAF 49/397 reads (12%) | SIFT tolerated (0.09); PolyPhen benign (0); catalogued as rs371943450; called by muse, mutect2, varscan2
- ZNF292 | c.6145del p.S2049Vfs*11 | Frame Shift Del (DEL) | VAF 136/141 reads (96%) | catalogued as rs764995318; called by mutect2, varscan2
- ZNF316 | c.1307C>T p.A436V | Missense Mutation (SNP) | VAF 314/603 reads (52%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.989); catalogued as rs907594755, COSV66385133; called by muse, mutect2, varscan2
- ZNF316 | c.1484G>A p.R495H | Missense Mutation (SNP) | VAF 103/709 reads (15%) | SIFT tolerated (0.2); PolyPhen probably damaging (0.961); catalogued as rs1418737347; called by muse, mutect2, varscan2
- ZNF341 | c.1648T>C p.S550P (on ENST00000375200 / NM_001282935.1; = p.S543P on NM_032819.4) | Missense Mutation (SNP) | VAF 145/490 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs917358675; called by muse, varscan2
- ZNF576 | c.152G>A p.R51H | Missense Mutation (SNP) | VAF 270/520 reads (52%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.958); catalogued as rs568418404, COSV100338249; called by muse, varscan2
- ZNF641 | c.932A>G p.Q311R | Missense Mutation (SNP) | VAF 272/549 reads (50%) | SIFT tolerated (0.11); PolyPhen benign (0.017); catalogued as rs1323322245; called by muse, mutect2, varscan2
- ZNF697 | c.445C>A p.L149M | Missense Mutation (SNP) | VAF 339/680 reads (50%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.727); catalogued as COSV101360057; called by muse, mutect2, varscan2
- ZNF700 | c.198del p.K66Nfs*22 | Frame Shift Del (DEL) | VAF 80/201 reads (40%) | catalogued as COSV54311507; called by mutect2, pindel, varscan2
- ZNF716 | c.23del p.P8Lfs*9 | Frame Shift Del (DEL) | VAF 203/496 reads (41%) | catalogued as COSV70783198; called by mutect2, pindel, varscan2
- ZNF831 | c.352G>A p.V118M | Missense Mutation (SNP) | VAF 292/851 reads (34%) | SIFT deleterious (0); PolyPhen possibly damaging (0.67); catalogued as rs777399101, COSV100926201, COSV64036993; called by muse, varscan2
- ZNF879 | c.1685A>G p.H562R | Missense Mutation (SNP) | VAF 86/186 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs1216562731; called by muse, mutect2, varscan2
- ZSCAN18 | c.1228G>A p.G410R | Missense Mutation (SNP) | VAF 276/561 reads (49%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.453); catalogued as COSV53729637, COSV99559285; called by muse, mutect2, varscan2
- ZSWIM2 | c.35G>A p.R12Q | Missense Mutation (SNP) | VAF 153/318 reads (48%) | SIFT deleterious (0); PolyPhen possibly damaging (0.651); catalogued as rs867074464; called by muse, mutect2, varscan2
- AATK | c.792C>A p.D264E (on ENST00000326724 / NM_001080395.3; = p.D161E on NM_004920.2) | Missense Mutation (SNP) | VAF 30/546 reads (5%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.729); called by muse, mutect2
- ABCC9 | c.1373T>C p.V458A | Missense Mutation (SNP) | VAF 158/361 reads (44%) | SIFT deleterious (0); PolyPhen benign (0.1); called by muse, mutect2, varscan2
- ABCD2 | c.1515G>A p.M505I | Missense Mutation (SNP) | VAF 83/195 reads (43%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.492); called by muse, mutect2, varscan2
- ABCG2 | c.473del p.N158Tfs*11 | Frame Shift Del (DEL) | VAF 194/489 reads (40%) | called by mutect2, pindel, varscan2
- AC011448.1 | c.110C>A p.A37D | Missense Mutation (SNP) | VAF 170/382 reads (45%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.972); called by muse, varscan2
- AC073111.3 | c.140C>T p.S47L | Missense Mutation (SNP) | VAF 363/744 reads (49%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.908); called by muse, mutect2, varscan2
- ACIN1 | c.532G>A p.G178R | Missense Mutation (SNP) | VAF 163/304 reads (54%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.013); called by muse, mutect2, varscan2
- ACMSD | c.55A>C p.K19Q | Missense Mutation (SNP) | VAF 88/230 reads (38%) | SIFT tolerated (0.41); PolyPhen benign (0); called by muse, mutect2, varscan2
- ACO1 | c.1396T>C p.Y466H | Missense Mutation (SNP) | VAF 207/207 reads (100%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.479); called by muse, mutect2, varscan2
- ACTN2 | c.2061C>G p.N687K | Missense Mutation (SNP) | VAF 222/437 reads (51%) | SIFT tolerated (0.39); PolyPhen benign (0.099); called by muse, mutect2, varscan2
- ADAMTS10 | c.2900G>A p.R967H | Missense Mutation (SNP) | VAF 276/574 reads (48%) | SIFT deleterious (0); PolyPhen possibly damaging (0.885); called by muse, mutect2, varscan2
- ADCK2 | c.1818del p.K607Nfs*57 | Frame Shift Del (DEL) | VAF 249/613 reads (41%) | called by mutect2, pindel, varscan2
- ADCY1 | c.818G>A p.R273Q | Missense Mutation (SNP) | VAF 144/338 reads (43%) | SIFT tolerated (0.84); PolyPhen benign (0.011); called by muse, mutect2, varscan2
- ADCY4 | c.2563A>G p.I855V | Missense Mutation (SNP) | VAF 206/414 reads (50%) | SIFT tolerated (0.28); PolyPhen benign (0.007); called by muse, varscan2
- ADGRE2 | c.2320A>G p.I774V | Missense Mutation (SNP) | VAF 153/331 reads (46%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.756); called by muse, mutect2, varscan2
- ADIPOR2 | c.722G>A p.C241Y | Missense Mutation (SNP) | VAF 48/368 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, varscan2
- ADPRS | c.310T>C p.F104L | Missense Mutation (SNP) | VAF 115/262 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); called by muse, mutect2, varscan2
- ADRB3 | c.728G>A p.G243D | Missense Mutation (SNP) | VAF 278/637 reads (44%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.493); called by muse, mutect2, varscan2
- AFF1 | c.2729_2730del p.S910Ffs*39 | Frame Shift Del (DEL) | VAF 156/402 reads (39%) | called by pindel, varscan2
- AKAP11 | c.5522C>T p.A1841V | Missense Mutation (SNP) | VAF 42/325 reads (13%) | SIFT tolerated (0.13); PolyPhen benign (0.049); called by muse, mutect2, varscan2
- AKTIP | c.382A>G p.I128V | Missense Mutation (SNP) | VAF 46/248 reads (19%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.759); called by muse, mutect2, varscan2
- ALOX12 | c.1919C>T p.A640V | Missense Mutation (SNP) | VAF 198/434 reads (46%) | SIFT tolerated (0.43); PolyPhen benign (0.05); called by muse, mutect2, varscan2
- ALOX15B | c.337del p.A113Rfs*83 | Frame Shift Del (DEL) | VAF 163/422 reads (39%) | called by mutect2, pindel, varscan2
- AMH | c.749T>C p.L250P | Missense Mutation (SNP) | VAF 447/950 reads (47%) | SIFT deleterious (0.02); PolyPhen benign (0.043); called by muse, mutect2, varscan2
- AMHR2 | c.1289-1G>T p.X430_splice | Splice Site (SNP) | VAF 112/313 reads (36%) | called by muse, mutect2, varscan2
- AMMECR1L | c.523C>T p.L175F | Missense Mutation (SNP) | VAF 157/320 reads (49%) | SIFT tolerated (0.49); PolyPhen benign (0.405); called by muse, mutect2, varscan2
- AMMECR1L | c.239A>T p.N80I | Missense Mutation (SNP) | VAF 226/461 reads (49%) | SIFT deleterious (0); PolyPhen benign (0.011); called by muse, mutect2, varscan2
- ANKDD1B | c.707del p.N236Tfs*20 | Frame Shift Del (DEL) | VAF 127/328 reads (39%) | called by mutect2, pindel, varscan2
- ANKRD12 | c.1313dup p.I439Dfs*10 | Frame Shift Ins (INS) | VAF 91/321 reads (28%) | called by mutect2, pindel, varscan2
- ANKRD34A | c.953C>A p.P318Q | Missense Mutation (SNP) | VAF 179/589 reads (30%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- AOC1 | c.1907_1909dup p.S636dup | In Frame Ins (INS) | VAF 224/504 reads (44%) | called by mutect2, varscan2
- APOB | c.12569_12572dup p.S4192* | Nonsense Mutation (INS) | VAF 117/265 reads (44%) | called by mutect2, varscan2
- APOB | c.4489G>A p.A1497T | Missense Mutation (SNP) | VAF 182/368 reads (49%) | SIFT tolerated (0.12); PolyPhen benign (0.037); called by muse, mutect2, varscan2
- ARAP3 | c.4397del p.P1466Lfs*16 | Frame Shift Del (DEL) | VAF 251/600 reads (42%) | called by mutect2, pindel, varscan2
- ARHGAP26 | c.2095G>C p.V699L | Missense Mutation (SNP) | VAF 323/675 reads (48%) | SIFT tolerated (0.75); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- ARHGEF1 | c.1030del p.L344Wfs*12 | Frame Shift Del (DEL) | VAF 178/470 reads (38%) | called by mutect2, pindel, varscan2
- ARHGEF10 | c.1159T>C p.S387P (on ENST00000398564; = p.S362P on NM_014629.4) | Missense Mutation (SNP) | VAF 138/303 reads (46%) | SIFT tolerated (0.13); PolyPhen benign (0.346); called by muse, mutect2, varscan2
- ARID1B | c.1823del p.P608Rfs*47 | Frame Shift Del (DEL) | VAF 284/399 reads (71%) | called by mutect2, pindel, varscan2
- ARID1B | c.4211G>T p.R1404M | Missense Mutation (SNP) | VAF 268/268 reads (100%) | SIFT deleterious (0); PolyPhen probably damaging (0.956); called by muse, mutect2, varscan2
- ARNTL | c.977C>A p.P326Q (on ENST00000403290 / NM_001297719.2; = p.P325Q on NM_001178.5 and 4 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 14/492 reads (3%) | SIFT tolerated (0.05); PolyPhen benign (0.296); called by muse, mutect2
- ARRDC5 | c.548G>A p.C183Y (on ENST00000381781; = p.C169Y on NM_001080523.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 149/314 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.917); called by muse, mutect2, varscan2
- ARVCF | c.622C>A p.L208M | Missense Mutation (SNP) | VAF 376/760 reads (49%) | SIFT tolerated (0.22); PolyPhen benign (0.38); called by muse, varscan2
- ASIC1 | c.14C>T p.A5V | Missense Mutation (SNP) | VAF 61/608 reads (10%) | SIFT tolerated (0.45); PolyPhen benign (0); called by muse, mutect2
- ASXL3 | c.727T>C p.W243R | Missense Mutation (SNP) | VAF 8/134 reads (6%) | SIFT tolerated, low confidence (0.44); PolyPhen possibly damaging (0.847); called by muse, mutect2
- ATP1A2 | c.229G>A p.A77T | Missense Mutation (SNP) | VAF 267/585 reads (46%) | SIFT tolerated (0.24); PolyPhen benign (0.011); called by muse, mutect2, varscan2
- ATP8A2 | c.3069G>T p.W1023C | Missense Mutation (SNP) | VAF 66/216 reads (31%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- ATRX | c.6125A>T p.Q2042L | Missense Mutation (SNP) | VAF 33/220 reads (15%) | SIFT deleterious (0); PolyPhen benign (0.223); called by muse, mutect2, varscan2
- AURKA | c.1141C>T p.P381S | Missense Mutation (SNP) | VAF 38/784 reads (5%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); called by muse, mutect2
- B4GALT4 | c.986A>G p.H329R | Missense Mutation (SNP) | VAF 159/345 reads (46%) | SIFT tolerated (0.86); PolyPhen benign (0); called by muse, mutect2, varscan2
- BAIAP2L2 | c.677C>T p.P226L | Missense Mutation (SNP) | VAF 27/878 reads (3%) | SIFT deleterious (0.04); PolyPhen benign (0.134); called by muse, mutect2
- BCL2L12 | c.500C>A p.P167H | Missense Mutation (SNP) | VAF 149/333 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- BICDL1 | c.1634C>T p.A545V | Missense Mutation (SNP) | VAF 31/627 reads (5%) | SIFT tolerated (0.33); PolyPhen benign (0.033); called by muse, mutect2
- BMPR2 | c.2920C>T p.R974C | Missense Mutation (SNP) | VAF 169/386 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- BRD3 | c.63_64del p.P24Gfs*51 | Frame Shift Del (DEL) | VAF 130/325 reads (40%) | called by pindel, varscan2
- BRF2 | c.475C>A p.L159I | Missense Mutation (SNP) | VAF 215/389 reads (55%) | SIFT tolerated (0.49); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- BRPF3 | c.2425dup p.D809Gfs*21 | Frame Shift Ins (INS) | VAF 225/322 reads (70%) | called by mutect2, pindel, varscan2
- BVES | c.79G>A p.V27M | Missense Mutation (SNP) | VAF 21/177 reads (12%) | SIFT tolerated (0.17); PolyPhen benign (0.02); called by muse, mutect2, varscan2
- C11orf65 | c.293C>T p.A98V | Missense Mutation (SNP) | VAF 18/304 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- C14orf93 | c.155G>A p.G52D | Missense Mutation (SNP) | VAF 224/419 reads (53%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- C17orf98 | c.223G>T p.G75* | Nonsense Mutation (SNP) | VAF 136/302 reads (45%) | called by muse, mutect2, varscan2
- C19orf18 | c.449A>G p.E150G | Missense Mutation (SNP) | VAF 195/391 reads (50%) | SIFT deleterious (0.01); PolyPhen benign (0.437); called by muse, mutect2, varscan2
- C19orf47 | c.698C>T p.A233V | Missense Mutation (SNP) | VAF 96/353 reads (27%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.592); called by muse, mutect2, varscan2
- C1orf127 | c.580G>T p.G194W | Missense Mutation (SNP) | VAF 16/468 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); called by muse, mutect2
- C1orf54 | c.204G>T p.K68N | Missense Mutation (SNP) | VAF 114/251 reads (45%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.494); called by muse, mutect2, varscan2
- C6 | c.2318G>T p.C773F | Missense Mutation (SNP) | VAF 119/255 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- CA11 | c.545C>G p.A182G | Missense Mutation (SNP) | VAF 172/321 reads (54%) | SIFT deleterious (0); PolyPhen probably damaging (0.939); called by muse, mutect2, varscan2
- CACHD1 | c.2717C>T p.T906I | Missense Mutation (SNP) | VAF 91/184 reads (49%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.969); called by muse, mutect2, varscan2
- CACNA1H | c.1972G>A p.E658K | Missense Mutation (SNP) | VAF 212/457 reads (46%) | SIFT tolerated (0.38); PolyPhen benign (0.11); called by muse, mutect2, varscan2
- CACNA2D3 | c.1949C>A p.A650E | Missense Mutation (SNP) | VAF 167/167 reads (100%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.918); called by muse, mutect2, varscan2
- CACUL1 | c.126del p.S43Rfs*45 | Frame Shift Del (DEL) | VAF 426/1034 reads (41%) | called by mutect2, pindel, varscan2
- CAPN13 | c.1802T>C p.F601S | Missense Mutation (SNP) | VAF 21/289 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); called by muse, mutect2
- CARMIL3 | c.2371G>T p.G791* | Nonsense Mutation (SNP) | VAF 217/485 reads (45%) | called by muse, mutect2, varscan2
- CASR | c.2499del p.S834Pfs*28 (on ENST00000490131; = p.S911Pfs*28 on NM_000388.4) | Frame Shift Del (DEL) | VAF 261/569 reads (46%) | called by mutect2, varscan2
- CAST | c.1795G>A p.A599T (on ENST00000341926; = p.A682T on NM_001750.7 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 101/200 reads (51%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.595); called by muse, mutect2, varscan2
- CBX6 | c.95G>T p.W32L | Missense Mutation (SNP) | VAF 58/420 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by mutect2, varscan2
- CCDC105 | c.1061T>C p.L354S | Missense Mutation (SNP) | VAF 128/285 reads (45%) | SIFT tolerated (0.33); PolyPhen benign (0.052); called by muse, mutect2, varscan2
- CCDC186 | c.1298del p.N433Tfs*5 | Frame Shift Del (DEL) | VAF 118/310 reads (38%) | called by mutect2, pindel, varscan2
- CCDC22 | c.1703G>A p.S568N | Missense Mutation (SNP) | VAF 242/527 reads (46%) | SIFT tolerated (0.28); PolyPhen benign (0.193); called by muse, mutect2, varscan2
- CD99 | c.142A>C p.S48R | Missense Mutation (SNP) | VAF 30/508 reads (6%) | SIFT deleterious (0.03); PolyPhen benign (0.053); called by muse, mutect2
- CDCA5 | c.484C>T p.R162C | Missense Mutation (SNP) | VAF 304/605 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.938); called by muse, mutect2, varscan2
- CDH15 | c.1310T>C p.L437P | Missense Mutation (SNP) | VAF 47/670 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2
- CDH2 | c.1030C>T p.Q344* | Nonsense Mutation (SNP) | VAF 17/110 reads (15%) | called by muse, mutect2, varscan2
- CDH23 | c.9962C>G p.T3321S | Missense Mutation (SNP) | VAF 122/662 reads (18%) | SIFT tolerated, low confidence (0.94); PolyPhen benign (0); called by muse, mutect2, varscan2
- CDKAL1 | c.1019C>A p.A340D | Missense Mutation (SNP) | VAF 125/125 reads (100%) | SIFT tolerated (0.39); PolyPhen benign (0.033); called by muse, mutect2, varscan2
- CDO1 | c.101A>G p.Q34R | Missense Mutation (SNP) | VAF 201/415 reads (48%) | SIFT tolerated (0.21); PolyPhen benign (0.047); called by muse, mutect2, varscan2
- CEACAM7 | c.169_171del p.N57del | In Frame Del (DEL) | VAF 200/418 reads (48%) | called by mutect2, pindel, varscan2
- CEP170 | c.2977_2980del p.K993Vfs*22 | Frame Shift Del (DEL) | VAF 162/558 reads (29%) | called by mutect2, pindel, varscan2
- CFAP54 | c.3772-1G>A p.X1258_splice | Splice Site (SNP) | VAF 72/148 reads (49%) | called by muse, mutect2, varscan2
- CFAP61 | c.31G>A p.V11I | Missense Mutation (SNP) | VAF 146/146 reads (100%) | SIFT tolerated (0.13); PolyPhen benign (0.058); called by muse, mutect2, varscan2
- CHD7 | c.8962del p.D2988Mfs*3 | Frame Shift Del (DEL) | VAF 240/347 reads (69%) | called by mutect2, pindel, varscan2
- CHRND | c.314del p.P105Rfs*77 | Frame Shift Del (DEL) | VAF 175/436 reads (40%) | called by mutect2, pindel, varscan2
- CIITA | c.1583T>C p.L528P | Missense Mutation (SNP) | VAF 216/466 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- CLIP4 | c.586T>C p.Y196H | Missense Mutation (SNP) | VAF 127/241 reads (53%) | SIFT tolerated (0.45); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- CNIH1 | c.394del p.Y132Tfs*6 | Frame Shift Del (DEL) | VAF 67/181 reads (37%) | called by mutect2, pindel, varscan2
- CNOT1 | c.5608C>T p.R1870C | Missense Mutation (SNP) | VAF 153/321 reads (48%) | SIFT deleterious (0); PolyPhen possibly damaging (0.871); called by muse, mutect2, varscan2
- CNOT4 | c.326del p.N109Tfs*6 | Frame Shift Del (DEL) | VAF 179/444 reads (40%) | called by mutect2, pindel, varscan2
- CNPPD1 | c.998_1000del p.L333del | In Frame Del (DEL) | VAF 188/482 reads (39%) | called by pindel, varscan2
- COL11A1 | c.4043G>C p.G1348A | Missense Mutation (SNP) | VAF 13/330 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2
- COL1A1 | c.2876G>A p.G959D | Missense Mutation (SNP) | VAF 54/616 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- COL6A2 | c.1297G>T p.G433C | Missense Mutation (SNP) | VAF 207/207 reads (100%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- COL8A1 | c.1507G>T p.G503W | Missense Mutation (SNP) | VAF 44/452 reads (10%) | SIFT deleterious (0.02); PolyPhen benign (0.056); called by muse, mutect2
- COX19 | c.270del p.K90Nfs*4 | Frame Shift Del (DEL) | VAF 131/347 reads (38%) | called by mutect2, pindel, varscan2
- CPAMD8 | c.5298G>T p.Q1766H (on ENST00000651564; = p.Q1719H on NM_015692.5) | Missense Mutation (SNP) | VAF 79/1026 reads (8%) | SIFT tolerated, low confidence (0.2); PolyPhen benign (0.001); called by muse, mutect2
- CPEB1 | c.1193G>C p.S398T (on ENST00000617958; = p.S338T on NM_030594.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 53/465 reads (11%) | SIFT tolerated (0.4); PolyPhen benign (0.029); called by muse, mutect2, varscan2
- CPNE6 | c.1104del p.N369Tfs*78 | Frame Shift Del (DEL) | VAF 178/431 reads (41%) | called by mutect2, pindel, varscan2
- CPS1 | c.3097G>T p.E1033* | Nonsense Mutation (SNP) | VAF 150/296 reads (51%) | called by muse, mutect2, varscan2
- CSK | c.164G>A p.G55D | Missense Mutation (SNP) | VAF 152/330 reads (46%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- CSMD1 | c.6061dup p.S2021Ffs*5 (on ENST00000520002; = p.S2020Ffs*5 on NM_033225.6) | Frame Shift Ins (INS) | VAF 105/281 reads (37%) | called by mutect2, pindel, varscan2
- CSMD2 | c.2918G>T p.S973I | Missense Mutation (SNP) | VAF 157/338 reads (46%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.932); called by muse, mutect2, varscan2
- CSNK1G3 | c.148G>A p.G50R | Missense Mutation (SNP) | VAF 15/301 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2
- CSRNP3 | c.579G>T p.K193N | Missense Mutation (SNP) | VAF 161/373 reads (43%) | SIFT deleterious (0); PolyPhen possibly damaging (0.714); called by muse, mutect2, varscan2
- CT55 | c.225del p.V76Lfs*14 | Frame Shift Del (DEL) | VAF 219/519 reads (42%) | called by mutect2, pindel, varscan2
- CTC1 | c.626C>A p.A209D | Missense Mutation (SNP) | VAF 141/288 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- CTDSP2 | c.777G>T p.E259D | Missense Mutation (SNP) | VAF 173/343 reads (50%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- CTNNA3 | c.926G>C p.S309T | Missense Mutation (SNP) | VAF 15/486 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); called by muse, mutect2
- CTU2 | c.1450C>A p.L484M | Missense Mutation (SNP) | VAF 368/754 reads (49%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- CUL1 | c.28del p.H10Tfs*3 | Frame Shift Del (DEL) | VAF 157/387 reads (41%) | called by mutect2, pindel, varscan2
- CUL4B | c.160G>A p.A54T | Missense Mutation (SNP) | VAF 277/543 reads (51%) | SIFT tolerated, low confidence (0.24); PolyPhen benign (0); called by muse, mutect2, varscan2
- CXADR | c.602del p.N201Mfs*27 | Frame Shift Del (DEL) | VAF 53/74 reads (72%) | called by mutect2, pindel, varscan2
- CYP4F22 | c.1454T>C p.L485S | Missense Mutation (SNP) | VAF 59/631 reads (9%) | SIFT deleterious (0); PolyPhen benign (0.191); called by muse, mutect2
- DBR1 | c.940A>C p.R314= | Splice Region (SNP) | VAF 112/227 reads (49%) | called by muse, mutect2, varscan2
- DCAF4L1 | c.94del p.S32Afs*3 | Frame Shift Del (DEL) | VAF 76/394 reads (19%) | called by mutect2, pindel, varscan2
- DDIT4L | c.130C>A p.L44I | Missense Mutation (SNP) | VAF 103/230 reads (45%) | SIFT tolerated (0.15); PolyPhen benign (0.058); called by muse, mutect2, varscan2
- DDX54 | c.1381C>T p.L461F | Missense Mutation (SNP) | VAF 258/588 reads (44%) | SIFT tolerated (0.17); PolyPhen benign (0.046); called by muse, mutect2, varscan2
- DEF6 | c.1069_1071del p.K357del | In Frame Del (DEL) | VAF 334/348 reads (96%) | called by mutect2, pindel, varscan2
- DEF6 | c.1788del p.S597Rfs*39 | Frame Shift Del (DEL) | VAF 261/370 reads (71%) | called by mutect2, pindel, varscan2
- DEFB108B | c.77_79del p.E26_I27delinsV | In Frame Del (DEL) | VAF 101/204 reads (50%) | called by mutect2, pindel, varscan2
- DENND10 | c.145C>A p.L49I | Missense Mutation (SNP) | VAF 158/551 reads (29%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); called by muse, varscan2
- DENND10 | c.863A>C p.E288A | Missense Mutation (SNP) | VAF 98/369 reads (27%) | SIFT deleterious (0.01); PolyPhen benign (0.132); called by muse, mutect2, varscan2
- DENND1C | c.1436del p.G479Afs*3 | Frame Shift Del (DEL) | VAF 160/474 reads (34%) | called by pindel, varscan2
- DGKZ | c.3110del p.P1037Qfs*38 (on ENST00000454345 / NM_001105540.2; = p.P849Qfs*38 on NM_003646.4) | Frame Shift Del (DEL) | VAF 238/582 reads (41%) | called by mutect2, pindel, varscan2
- DHX30 | c.2530A>G p.N844D (on ENST00000445061 / NM_138615.3; = p.N805D on NM_014966.3) | Missense Mutation (SNP) | VAF 246/249 reads (99%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- DMKN | c.464G>A p.G155D | Missense Mutation (SNP) | VAF 72/478 reads (15%) | SIFT deleterious (0.01); PolyPhen benign (0.114); called by muse, mutect2, varscan2
- DNAAF5 | c.780G>T p.Q260H | Missense Mutation (SNP) | VAF 39/239 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.884); called by muse, mutect2, varscan2
- DNAH11 | c.5719G>T p.G1907* | Nonsense Mutation (SNP) | VAF 18/454 reads (4%) | called by muse, mutect2
- DNAH8 | c.2775del p.Q926Nfs*19 | Frame Shift Del (DEL) | VAF 156/221 reads (71%) | called by mutect2, pindel, varscan2
- DNAJC27 | c.214A>G p.M72V | Missense Mutation (SNP) | VAF 154/295 reads (52%) | SIFT tolerated (0.12); PolyPhen benign (0.014); called by muse, mutect2, varscan2
- DOC2B | c.362C>T p.S121L | Missense Mutation (SNP) | VAF 211/420 reads (50%) | SIFT deleterious (0); PolyPhen possibly damaging (0.825); called by muse, mutect2, varscan2
- DOLPP1 | c.157T>A p.F53I | Missense Mutation (SNP) | VAF 230/230 reads (100%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.496); called by muse, mutect2, varscan2
- DPEP3 | c.506C>A p.A169D | Missense Mutation (SNP) | VAF 121/282 reads (43%) | SIFT tolerated (0.23); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- DPP10 | c.217G>T p.D73Y | Missense Mutation (SNP) | VAF 111/219 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- DSPP | c.3705C>A p.S1235R | Missense Mutation (SNP) | VAF 204/414 reads (49%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.084); called by mutect2, varscan2
- DXO | c.399del p.H134Tfs*2 | Frame Shift Del (DEL) | VAF 309/433 reads (71%) | called by mutect2, pindel, varscan2
- E2F7 | c.2186del p.P729Lfs*53 | Frame Shift Del (DEL) | VAF 167/452 reads (37%) | called by mutect2, pindel, varscan2
- EBF3 | c.1277G>A p.G426D (on ENST00000355311 / NM_001375392.1; = p.G417D on NM_001005463.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 246/493 reads (50%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.066); called by muse, mutect2, varscan2
- EDRF1 | c.1734del p.K578Nfs*32 (on ENST00000356792 / NM_001202438.2; = p.K544Nfs*32 on NM_015608.2) | Frame Shift Del (DEL) | VAF 85/208 reads (41%) | called by mutect2, pindel, varscan2
- EFR3B | c.1921A>G p.R641G | Missense Mutation (SNP) | VAF 126/265 reads (48%) | SIFT tolerated (0.44); PolyPhen benign (0.116); called by muse, varscan2
- EIF2S3B | c.1213A>G p.M405V | Missense Mutation (SNP) | VAF 263/536 reads (49%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.59); called by muse, mutect2, varscan2
- EIF5B | c.2368C>T p.R790* | Nonsense Mutation (SNP) | VAF 92/195 reads (47%) | called by muse, mutect2, varscan2
- EMILIN3 | c.799C>A p.Q267K | Missense Mutation (SNP) | VAF 268/810 reads (33%) | SIFT tolerated (0.18); PolyPhen benign (0.01); called by muse, mutect2, varscan2
- ENOX2 | c.1270C>T p.Q424* (on ENST00000338144 / NM_001382520.1; = p.Q395* on NM_006375.3 and 2 other RefSeq transcripts) | Nonsense Mutation (SNP) | VAF 186/399 reads (47%) | called by muse, mutect2, varscan2
- EPB41L3 | c.201G>T p.Q67H | Missense Mutation (SNP) | VAF 99/243 reads (41%) | SIFT tolerated (0.08); PolyPhen benign (0.125); called by mutect2, varscan2
- EPOP | c.77G>T p.R26L | Missense Mutation (SNP) | VAF 32/1056 reads (3%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.011); called by muse, mutect2
- EPRS1 | c.2986G>A p.G996R | Missense Mutation (SNP) | VAF 164/346 reads (47%) | SIFT tolerated (0.14); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- ERBB2 | c.2005del p.V669Wfs*32 | Frame Shift Del (DEL) | VAF 136/455 reads (30%) | called by mutect2, pindel, varscan2
- ERFL | c.280G>A p.D94N | Missense Mutation (SNP) | VAF 72/380 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); called by muse, mutect2, varscan2
- ETFA | c.526G>T p.A176S | Missense Mutation (SNP) | VAF 111/357 reads (31%) | SIFT tolerated (0.08); PolyPhen benign (0.099); called by muse, mutect2, varscan2
- ETS2 | c.51_52del p.N17Kfs*13 | Frame Shift Del (DEL) | VAF 18/107 reads (17%) | called by mutect2, pindel, varscan2
- EYA2 | c.252T>A p.Y84* | Nonsense Mutation (SNP) | VAF 33/750 reads (4%) | called by muse, mutect2
- F8 | c.5969A>G p.Y1990C | Missense Mutation (SNP) | VAF 180/180 reads (100%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- FAM124B | c.880T>C p.S294P | Missense Mutation (SNP) | VAF 238/459 reads (52%) | SIFT tolerated (0.09); PolyPhen benign (0.139); called by muse, mutect2, varscan2
- FAM178B | c.338del p.P113Rfs*31 | Frame Shift Del (DEL) | VAF 268/647 reads (41%) | called by mutect2, pindel, varscan2
- FAM189A1 | c.1280T>G p.L427R | Missense Mutation (SNP) | VAF 271/536 reads (51%) | SIFT tolerated (0.06); PolyPhen benign (0.202); called by muse, mutect2, varscan2
- FAM200A | c.790G>A p.A264T | Missense Mutation (SNP) | VAF 12/441 reads (3%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.459); called by muse, mutect2
- FAM71A | c.1178del p.P393Lfs*12 | Frame Shift Del (DEL) | VAF 234/571 reads (41%) | called by mutect2, pindel, varscan2
- FANCE | c.1037C>T p.T346I | Missense Mutation (SNP) | VAF 241/241 reads (100%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.493); called by muse, mutect2, varscan2
- FASTK | c.1603C>T p.Q535* | Nonsense Mutation (SNP) | VAF 39/708 reads (6%) | called by muse, mutect2
- FBN1 | c.172G>A p.V58I | Missense Mutation (SNP) | VAF 13/360 reads (4%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.956); called by muse, mutect2
- FER1L5 | c.5267G>T p.R1756M (on ENST00000623019; = p.X1720_splice on NM_001293083.2) | Missense Mutation (SNP) | VAF 89/279 reads (32%) | SIFT deleterious (0); PolyPhen possibly damaging (0.832); called by muse, mutect2, varscan2
- FFAR2 | c.677T>C p.V226A | Missense Mutation (SNP) | VAF 247/500 reads (49%) | SIFT tolerated (1); PolyPhen benign (0.049); called by muse, mutect2, varscan2
- FGA | c.1210A>T p.R404W | Missense Mutation (SNP) | VAF 18/472 reads (4%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.924); called by muse, mutect2
- FIZ1 | c.843G>T p.E281D | Missense Mutation (SNP) | VAF 141/844 reads (17%) | SIFT tolerated (0.42); PolyPhen benign (0.021); called by muse, mutect2, varscan2
- FKBP4 | c.176G>A p.G59D | Missense Mutation (SNP) | VAF 25/528 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- FLG2 | c.3489_3501del p.S1164Nfs*59 | Frame Shift Del (DEL) | VAF 196/466 reads (42%) | called by mutect2, pindel, varscan2
- FMNL2 | c.662T>C p.V221A | Missense Mutation (SNP) | VAF 40/345 reads (12%) | SIFT deleterious (0); PolyPhen benign (0.131); called by muse, mutect2, varscan2
- FN1 | c.2258A>G p.E753G | Missense Mutation (SNP) | VAF 181/357 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- FNDC11 | c.786del p.V263Wfs*59 | Frame Shift Del (DEL) | VAF 206/983 reads (21%) | called by mutect2, pindel, varscan2
- FNDC7 | c.125G>T p.S42I | Missense Mutation (SNP) | VAF 73/394 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- FNTA | c.1073A>G p.Y358C | Missense Mutation (SNP) | VAF 174/370 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- FOXE3 | c.676C>T p.Q226* | Nonsense Mutation (SNP) | VAF 343/691 reads (50%) | called by muse, mutect2, varscan2
- FOXI2 | c.766G>A p.A256T | Missense Mutation (SNP) | VAF 116/642 reads (18%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.852); called by muse, varscan2
- FREM2 | c.9452G>A p.S3151N | Missense Mutation (SNP) | VAF 19/406 reads (5%) | SIFT tolerated, low confidence (0.46); PolyPhen benign (0.06); called by muse, mutect2
- FUT1 | c.308C>T p.A103V | Missense Mutation (SNP) | VAF 307/601 reads (51%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.771); called by muse, mutect2, varscan2
- FZD5 | c.134G>A p.G45D | Missense Mutation (SNP) | VAF 34/746 reads (5%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.998); called by muse, mutect2
- GALNT3 | c.837C>T p.H279= | Splice Region (SNP) | VAF 17/487 reads (3%) | called by muse, mutect2
- GANAB | c.68del p.L23* | Frame Shift Del (DEL) | VAF 185/439 reads (42%) | called by mutect2, pindel, varscan2
- GAP43 | c.122G>A p.S41N | Missense Mutation (SNP) | VAF 146/330 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- GDF6 | c.1064G>A p.S355N | Missense Mutation (SNP) | VAF 27/580 reads (5%) | SIFT tolerated (0.06); PolyPhen benign (0.413); called by muse, mutect2
- GDPD2 | c.1558G>T p.G520W | Missense Mutation (SNP) | VAF 226/491 reads (46%) | SIFT tolerated (0.1); PolyPhen benign (0.171); called by muse, mutect2, varscan2
- GDPGP1 | c.346A>G p.R116G | Missense Mutation (SNP) | VAF 192/449 reads (43%) | SIFT tolerated (0.06); PolyPhen benign (0.051); called by muse, varscan2
- GEMIN7 | c.218T>C p.M73T | Missense Mutation (SNP) | VAF 20/588 reads (3%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.628); called by muse, mutect2
- GIPR | c.1276C>A p.R426S | Missense Mutation (SNP) | VAF 119/730 reads (16%) | SIFT tolerated (0.4); PolyPhen benign (0); called by muse, mutect2, varscan2
- GLRA4 | c.436A>G p.T146A | Missense Mutation (SNP) | VAF 326/630 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); called by muse, mutect2, varscan2
- GLUD2 | c.175G>T p.D59Y | Missense Mutation (SNP) | VAF 36/764 reads (5%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.804); called by muse, mutect2
- GMIP | c.1366G>T p.G456C | Missense Mutation (SNP) | VAF 184/380 reads (48%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.963); called by muse, mutect2, varscan2
- GPR108 | c.1141G>A p.A381T (on ENST00000264080 / NM_001080452.1; = p.A139T on NM_020171.2) | Missense Mutation (SNP) | VAF 141/284 reads (50%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- GPR152 | c.1169C>A p.P390Q | Missense Mutation (SNP) | VAF 81/607 reads (13%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- GPR157 | c.391del p.V131Sfs*12 | Frame Shift Del (DEL) | VAF 102/267 reads (38%) | called by mutect2, pindel, varscan2
- GPR160 | c.715del p.I239Yfs*22 | Frame Shift Del (DEL) | VAF 37/295 reads (13%) | called by mutect2, pindel, varscan2
- GREB1L | c.1937G>A p.C646Y | Missense Mutation (SNP) | VAF 14/426 reads (3%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2
- GRIA4 | c.778A>G p.T260A | Missense Mutation (SNP) | VAF 148/338 reads (44%) | SIFT deleterious (0); PolyPhen possibly damaging (0.727); called by muse, mutect2
- GRIK1 | c.646C>T p.L216F | Missense Mutation (SNP) | VAF 14/186 reads (8%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.997); called by muse, mutect2
- GRK1 | c.203G>A p.G68D | Missense Mutation (SNP) | VAF 274/578 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- GRM7 | c.1767del p.W590Gfs*3 | Frame Shift Del (DEL) | VAF 169/429 reads (39%) | called by mutect2, pindel, varscan2
- GSG1L | c.551G>A p.G184D (on ENST00000447459 / NM_001109763.2; = p.G29D on NM_144675.2) | Missense Mutation (SNP) | VAF 104/222 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.935); called by muse, mutect2, varscan2
- GSTK1 | c.271A>G p.M91V | Missense Mutation (SNP) | VAF 132/250 reads (53%) | SIFT tolerated (0.47); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- GUCA1C | c.176A>G p.Q59R | Missense Mutation (SNP) | VAF 100/218 reads (46%) | SIFT tolerated (0.12); PolyPhen benign (0.028); called by muse, varscan2
- H3Y1 | c.263C>T p.A88V | Missense Mutation (SNP) | VAF 186/392 reads (47%) | SIFT deleterious, low confidence (0.05); PolyPhen possibly damaging (0.455); called by muse, mutect2, varscan2
- HEPH | c.875G>A p.W292* (on ENST00000343002; = p.W25* on NM_014799.4 and 1 other RefSeq transcript) | Nonsense Mutation (SNP) | VAF 37/788 reads (5%) | called by muse, mutect2
- HS3ST3A1 | c.898C>T p.R300C | Missense Mutation (SNP) | VAF 74/321 reads (23%) | SIFT deleterious (0.03); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- HSPA4L | c.1006A>T p.S336C | Missense Mutation (SNP) | VAF 18/209 reads (9%) | SIFT tolerated (0.08); PolyPhen benign (0); called by muse, mutect2
- HTT | c.7091C>T p.A2364V | Missense Mutation (SNP) | VAF 184/435 reads (42%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.99); called by muse, mutect2, varscan2
- HUWE1 | c.12610_12612del p.K4204del | In Frame Del (DEL) | VAF 158/327 reads (48%) | called by pindel, varscan2
- IFI16 | c.679dup p.I227Nfs*42 | Frame Shift Ins (INS) | VAF 120/260 reads (46%) | called by mutect2, varscan2
- IFRD1 | c.916del p.Y306Mfs*7 | Frame Shift Del (DEL) | VAF 64/140 reads (46%) | called by mutect2, varscan2
- IGKV6D-21 | c.292G>A p.E98K | Missense Mutation (SNP) | VAF 69/414 reads (17%) | SIFT tolerated (0.07); PolyPhen benign (0.143); called by muse, mutect2, varscan2
- IGSF21 | c.908C>T p.A303V | Missense Mutation (SNP) | VAF 283/599 reads (47%) | SIFT deleterious (0); PolyPhen possibly damaging (0.57); called by muse, mutect2, varscan2
- IGSF9B | c.2573T>C p.F858S | Missense Mutation (SNP) | VAF 358/763 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- IL31RA | c.1291T>C p.Y431H | Missense Mutation (SNP) | VAF 147/328 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- INAVA | c.1346C>T p.A449V | Missense Mutation (SNP) | VAF 342/701 reads (49%) | SIFT tolerated (0.21); PolyPhen benign (0.077); called by muse, mutect2, varscan2
- INF2 | c.1736_1737del p.X579_splice | Splice Site (DEL) | VAF 50/364 reads (14%) | called by pindel, varscan2
- IRAG2 | c.4107G>T p.W1369C (on ENST00000636465; = p.W414C on NM_006152.4 and 7 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 62/149 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- ITGA10 | c.3187G>T p.V1063F | Missense Mutation (SNP) | VAF 26/303 reads (9%) | SIFT tolerated (0.48); PolyPhen benign (0.072); called by muse, mutect2
- ITGAE | c.2381del p.P794Lfs*59 | Frame Shift Del (DEL) | VAF 75/585 reads (13%) | called by mutect2, pindel, varscan2
- ITSN1 | c.299del p.P100Lfs*3 | Frame Shift Del (DEL) | VAF 35/212 reads (17%) | called by mutect2, pindel, varscan2
- KANK1 | c.1657C>T p.P553S | Missense Mutation (SNP) | VAF 223/223 reads (100%) | SIFT deleterious (0.01); PolyPhen benign (0.203); called by muse, mutect2, varscan2
- KANK3 | c.49del p.R17Afs*36 | Frame Shift Del (DEL) | VAF 285/659 reads (43%) | called by mutect2, pindel, varscan2
- KCMF1 | c.11A>G p.H4R | Missense Mutation (SNP) | VAF 304/598 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (0.933); called by muse, mutect2, varscan2
- KCNG2 | c.80G>A p.R27H | Missense Mutation (SNP) | VAF 397/397 reads (100%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.988); called by muse, mutect2, varscan2
- KCNT1 | c.1383C>A p.D461E (on ENST00000488444; = p.D480E on NM_020822.3) | Missense Mutation (SNP) | VAF 116/267 reads (43%) | SIFT deleterious (0); PolyPhen possibly damaging (0.867); called by muse, mutect2, varscan2
- KDM6A | c.1892C>A p.P631Q | Missense Mutation (SNP) | VAF 201/454 reads (44%) | SIFT deleterious, low confidence (0.05); PolyPhen benign (0.06); called by muse, mutect2, varscan2
- KIF13A | c.1149G>T p.Q383H | Missense Mutation (SNP) | VAF 146/147 reads (99%) | SIFT tolerated (0.2); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- KIF15 | c.626C>T p.A209V | Missense Mutation (SNP) | VAF 8/155 reads (5%) | SIFT deleterious (0); PolyPhen possibly damaging (0.667); called by muse, mutect2
- KIF3C | c.512C>A p.P171H | Missense Mutation (SNP) | VAF 220/434 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- KLF10 | c.79A>G p.M27V | Missense Mutation (SNP) | VAF 17/333 reads (5%) | SIFT tolerated (0.4); PolyPhen benign (0); called by muse, mutect2
- KLHDC7B | c.587A>T p.E196V (on ENST00000395676; = p.E837V on NM_138433.5) | Missense Mutation (SNP) | VAF 324/698 reads (46%) | SIFT deleterious (0); PolyPhen benign (0.376); called by muse, mutect2, varscan2
- KLHL25 | c.313G>A p.A105T | Missense Mutation (SNP) | VAF 262/583 reads (45%) | SIFT tolerated (0.08); PolyPhen benign (0.423); called by muse, mutect2
- KLHL26 | c.1104del p.Q369Sfs*22 | Frame Shift Del (DEL) | VAF 298/767 reads (39%) | called by mutect2, pindel, varscan2
- KMT2B | c.7688C>T p.A2563V | Missense Mutation (SNP) | VAF 164/369 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.913); called by muse, mutect2, varscan2
- KMT2D | c.7061del p.P2354Lfs*30 | Frame Shift Del (DEL) | VAF 311/724 reads (43%) | called by mutect2, pindel, varscan2
- KPNA3 | c.1310del p.N437Tfs*3 | Frame Shift Del (DEL) | VAF 170/446 reads (38%) | called by mutect2, pindel, varscan2
- KRT83 | c.1406G>T p.S469I | Missense Mutation (SNP) | VAF 283/605 reads (47%) | SIFT deleterious (0.01); PolyPhen benign (0.181); called by muse, mutect2, varscan2
- KRTAP10-8 | c.616T>C p.S206P | Missense Mutation (SNP) | VAF 369/372 reads (99%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.761); called by muse, mutect2, varscan2
- KSR2 | c.718C>T p.P240S | Missense Mutation (SNP) | VAF 390/782 reads (50%) | SIFT tolerated (0.5); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- L1CAM | c.1274C>A p.P425Q | Missense Mutation (SNP) | VAF 78/471 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.781); called by muse, mutect2, varscan2
- LAMA1 | c.211G>T p.G71C | Missense Mutation (SNP) | VAF 55/359 reads (15%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.813); called by muse, mutect2, varscan2
- LAS1L | c.545A>C p.K182T | Missense Mutation (SNP) | VAF 241/484 reads (50%) | SIFT deleterious (0); PolyPhen benign (0.02); called by muse, mutect2, varscan2
- LENG9 | c.79_81del p.F27del | In Frame Del (DEL) | VAF 252/650 reads (39%) | called by pindel, varscan2
- LETMD1 | c.625G>A p.G209R | Missense Mutation (SNP) | VAF 44/341 reads (13%) | SIFT tolerated (0.62); PolyPhen benign (0); called by muse, mutect2, varscan2
- LHX1 | c.695G>A p.R232H | Missense Mutation (SNP) | VAF 189/397 reads (48%) | SIFT deleterious (0.05); PolyPhen benign (0.037); called by muse, mutect2, varscan2
- LILRB4 | c.930G>T p.K310N | Missense Mutation (SNP) | VAF 75/159 reads (47%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.624); called by muse, mutect2, varscan2
- LMF1 | c.1259T>A p.I420N | Missense Mutation (SNP) | VAF 236/463 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (0.925); called by muse, mutect2, varscan2
- LONRF1 | c.1514G>A p.R505H | Missense Mutation (SNP) | VAF 120/298 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- LRCH3 | c.2207A>G p.Q736R | Missense Mutation (SNP) | VAF 45/262 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); called by muse, mutect2, varscan2
- LRP2 | c.9250A>G p.N3084D | Missense Mutation (SNP) | VAF 83/428 reads (19%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- LRP8 | c.745G>A p.G249S | Missense Mutation (SNP) | VAF 467/962 reads (49%) | SIFT tolerated (0.59); PolyPhen possibly damaging (0.638); called by muse, mutect2
- LRRC43 | c.709C>A p.L237M | Missense Mutation (SNP) | VAF 172/393 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- LRRC7 | c.2812A>G p.N938D (on ENST00000651989 / NM_001370785.2; = p.N905D on NM_001330635.3 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 172/395 reads (44%) | SIFT tolerated, low confidence (0.06); PolyPhen possibly damaging (0.458); called by muse, mutect2, varscan2
- LRRC74A | c.814-1G>T p.X272_splice | Splice Site (SNP) | VAF 16/311 reads (5%) | called by muse, mutect2
- LRRCC1 | c.2746C>G p.H916D | Missense Mutation (SNP) | VAF 28/273 reads (10%) | SIFT deleterious (0.02); PolyPhen benign (0.035); called by muse, mutect2
- LRRK2 | c.6725C>T p.T2242I | Missense Mutation (SNP) | VAF 92/233 reads (39%) | SIFT deleterious (0.04); PolyPhen benign (0.265); called by muse, mutect2, varscan2
- LUZP1 | c.2516G>A p.S839N | Missense Mutation (SNP) | VAF 47/553 reads (8%) | SIFT tolerated (0.27); PolyPhen benign (0.009); called by muse, mutect2
- LZTS2 | c.1179G>T p.Q393H | Missense Mutation (SNP) | VAF 46/780 reads (6%) | SIFT deleterious (0); PolyPhen possibly damaging (0.841); called by muse, mutect2
- MAGEB18 | c.628A>G p.N210D | Missense Mutation (SNP) | VAF 268/523 reads (51%) | SIFT deleterious (0); PolyPhen possibly damaging (0.534); called by muse, mutect2, varscan2
- MAGEB6B | c.1171T>C p.Y391H | Missense Mutation (SNP) | VAF 208/454 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- MAML3 | c.1321A>G p.N441D | Missense Mutation (SNP) | VAF 195/423 reads (46%) | SIFT deleterious (0.03); PolyPhen benign (0.321); called by muse, mutect2, varscan2
- MAPK1IP1L | c.124A>G p.N42D | Missense Mutation (SNP) | VAF 209/406 reads (51%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.125); called by muse, mutect2, varscan2
- MARCHF5 | c.106A>G p.R36G | Missense Mutation (SNP) | VAF 51/403 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.955); called by muse, mutect2, varscan2
- MARCOL | c.812G>A p.S271N | Missense Mutation (SNP) | VAF 16/380 reads (4%) | SIFT tolerated (0.23); PolyPhen possibly damaging (0.691); called by muse, mutect2
- MARS1 | c.1022C>T p.A341V | Missense Mutation (SNP) | VAF 22/398 reads (6%) | SIFT tolerated (0.07); PolyPhen benign (0.005); called by muse, mutect2
672 further variants in this file (258 protein-altering or splice-affecting, 352 silent, 62 other) are not listed here.
